Somatic mutation profile of tumor specimen ALCH-B29Y-TTP1-A (aliquot ALCH-B29Y-TTP1-A-1-0-D-A775-36) from ALCHEMIST case ALCH-B29Y, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.3 years (22,037 days).
Specimen ALCH-B29Y-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 244d8db6-ebf8-4a24-89bd-e8f50db2b5e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B29Y-NB1-A (Blood Derived Normal), aliquot ALCH-B29Y-NB1-A-1-0-D-A775-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/92c46599-b4ac-4070-aabc-4c1bf5927c28

The open-access MAF lists 827 somatic variants for this specimen: 560 protein-altering or splice-affecting, 157 silent, 110 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 487, Silent 157, Intron 55, Nonsense Mutation 37, RNA 16, 5'UTR 15, Splice Site 15, 3'UTR 12, Frame Shift Del 11, 5'Flank 7, Splice Region 6, 3'Flank 5.

Variants (750 of 827; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FGFR3 | c.*668A>G | 3'UTR (SNP) | VAF 23/90 reads (26%) | catalogued as rs80053154, CM970530, COSV53408774; ClinVar: pathogenic; called by muse, mutect2, varscan2
- PTEN | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 14/68 reads (21%) | catalogued as rs1060500116, CM043772, CM110148, COSV64294267, COSV64296058, COSV64298758; ClinVar: pathogenic; called by muse, varscan2
- TP53 | c.535C>T p.H179Y | Missense Mutation (SNP) | VAF 58/190 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs587780070, CM067054, COSV52662617, COSV52668276, COSV52699993; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AATK | c.1418G>A p.R473Q (on ENST00000326724 / NM_001080395.3; = p.R370Q on NM_004920.2) | Missense Mutation (SNP) | VAF 12/131 reads (9%) | SIFT tolerated (0.32); PolyPhen benign (0.031); catalogued as rs888195768; called by muse, mutect2
- ACCSL | c.346C>G p.Q116E | Missense Mutation (SNP) | VAF 52/246 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.038); catalogued as rs1260930742; called by muse, mutect2, varscan2
- ACTR10 | c.658C>A p.L220M | Missense Mutation (SNP) | VAF 25/172 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.241); catalogued as COSV54300263; called by muse, mutect2, varscan2
- ADCY6 | c.2917C>G p.Q973E | Missense Mutation (SNP) | VAF 15/278 reads (5%) | SIFT tolerated (0.32); PolyPhen benign (0.025); catalogued as COSV57166522; called by muse, mutect2
- ADGRB3 | c.4061C>T p.P1354L | Missense Mutation (SNP) | VAF 60/346 reads (17%) | SIFT tolerated (0.71); PolyPhen benign (0.007); catalogued as COSV53238377; called by muse, mutect2, varscan2
- ADGRG2 | c.1613C>A p.S538* (on ENST00000379869 / NM_001079858.3; = p.S535* on NM_005756.4) | Nonsense Mutation (SNP) | VAF 20/190 reads (11%) | catalogued as COSV61341559; called by muse, mutect2, varscan2
- AFF2 | c.124G>C p.D42H | Missense Mutation (SNP) | VAF 33/143 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.477); catalogued as COSV60664395, COSV60668509; called by muse, mutect2, varscan2
- ALOX5 | c.1365C>G p.I455M | Missense Mutation (SNP) | VAF 21/135 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.228); catalogued as rs201465951; called by muse, mutect2, varscan2
- AMER1 | c.3067C>A p.P1023T | Missense Mutation (SNP) | VAF 6/65 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.638); catalogued as rs1007994686; called by muse, mutect2
- ANKRA2 | c.353C>G p.S118C | Missense Mutation (SNP) | VAF 51/239 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57142090; called by muse, mutect2, varscan2
- ANKRD26 | c.2930G>T p.R977L | Missense Mutation (SNP) | VAF 41/268 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.129); catalogued as COSV65774563; called by muse, mutect2, varscan2
- ANO6 | c.1246G>T p.E416* | Nonsense Mutation (SNP) | VAF 84/449 reads (19%) | catalogued as COSV100263881; called by muse, mutect2, varscan2
- APCS | c.190C>G p.R64G | Missense Mutation (SNP) | VAF 40/263 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99661129; called by muse, mutect2, varscan2
- ARHGAP11A | c.1947G>T p.L649F | Missense Mutation (SNP) | VAF 9/90 reads (10%) | SIFT tolerated (0.09); PolyPhen benign (0.38); catalogued as COSV55708211; called by muse, mutect2, varscan2
- ARHGAP32 | c.3772A>T p.T1258S (on ENST00000310343 / NM_001378025.1; = p.T909S on NM_014715.4) | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); catalogued as COSV59853016; called by muse, mutect2, varscan2
- ASCL3 | c.87C>G p.F29L | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.675); catalogued as rs202112150; called by muse, mutect2, varscan2
- ATAD5 | c.1609G>T p.E537* | Nonsense Mutation (SNP) | VAF 9/69 reads (13%) | catalogued as COSV100430231; called by mutect2, varscan2
- ATXN7L2 | c.1741C>T p.L581F | Missense Mutation (SNP) | VAF 63/275 reads (23%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV60204865; called by muse, mutect2, varscan2
- B2M | c.289G>A p.E97K | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT tolerated (0.52); PolyPhen benign (0.006); catalogued as COSV62564013; called by muse, mutect2
- B3GAT1 | c.943G>A p.E315K | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.625); catalogued as COSV56997768; called by muse, mutect2, varscan2
- CABP1 | c.724G>T p.D242Y (on ENST00000316803 / NM_001033677.1; = p.D39Y on NM_004276.5) | Missense Mutation (SNP) | VAF 30/204 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56457819; called by muse, mutect2, varscan2
- CAPN13 | c.899G>T p.R300L | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT tolerated (0.61); PolyPhen benign (0.308); catalogued as COSV54429237; called by muse, mutect2, varscan2
- CBX4 | c.1439C>T p.T480M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT deleterious (0.05); PolyPhen benign (0.001); catalogued as COSV53966613; called by muse, mutect2, varscan2
- CCDC14 | c.130C>A p.L44M | Missense Mutation (SNP) | VAF 42/162 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as COSV68765750; called by muse, mutect2, varscan2
- CCDC85C | c.527C>T p.S176F | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs1464965529; called by muse, mutect2, varscan2
- CCDC90B | c.328A>G p.I110V | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs1243388345; called by muse, mutect2, varscan2
- CCM2 | c.1075G>C p.E359Q | Missense Mutation (SNP) | VAF 74/356 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV51848443; called by muse, mutect2, varscan2
- CCPG1 | c.1909C>T p.Q637* | Nonsense Mutation (SNP) | VAF 15/113 reads (13%) | catalogued as COSV99380670; called by muse, mutect2, varscan2
- CDH9 | c.758C>G p.T253R | Missense Mutation (SNP) | VAF 33/426 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs774752049, COSV50399519; called by muse, mutect2
- CEP350 | c.6892C>G p.L2298V | Missense Mutation (SNP) | VAF 5/61 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV62601052; called by muse, mutect2
- CER1 | c.275G>C p.R92T | Missense Mutation (SNP) | VAF 44/258 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as rs574648627; called by muse, mutect2, varscan2
- CIBAR2 | c.587C>A p.A196E | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV73320600; called by muse, mutect2, varscan2
- CLEC11A | c.796C>G p.R266G | Missense Mutation (SNP) | VAF 56/213 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV51574922, COSV51574939; called by muse, mutect2, varscan2
- CLEC18B | c.1013A>G p.K338R | Missense Mutation (SNP) | VAF 33/347 reads (10%) | SIFT tolerated, low confidence (0.48); PolyPhen benign (0.005); catalogued as rs771558391; called by muse, mutect2
- CNGA2 | c.1604G>C p.R535P | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61706168; called by muse, mutect2, varscan2
- COL4A2 | c.952C>A p.Q318K | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0.253); catalogued as COSV64628383; called by muse, mutect2, varscan2
- COQ3 | c.954G>A p.W318* | Nonsense Mutation (SNP) | VAF 33/219 reads (15%) | catalogued as rs763813636, COSV54639818; called by muse, mutect2, varscan2
- CRYBG1 | c.2440G>C p.E814Q | Missense Mutation (SNP) | VAF 16/100 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.098); catalogued as rs1474161796, COSV64813101; called by muse, mutect2, varscan2
- CRYBG2 | c.4019C>T p.S1340L | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV57487903; called by muse, mutect2, varscan2
- CSNK2A3 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 19/420 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1408970183; called by muse, mutect2
- CTTN | c.1052G>C p.R351T | Missense Mutation (SNP) | VAF 10/149 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.821); catalogued as COSV57235631; called by muse, mutect2
- CXCL16 | c.216G>T p.T72= | Splice Region (SNP) | VAF 11/71 reads (15%) | catalogued as rs1263458010; called by muse, mutect2, varscan2
- CYP4F2 | c.815A>G p.Q272R | Missense Mutation (SNP) | VAF 88/379 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.077); catalogued as rs763970910; called by muse, mutect2, varscan2
- DDX27 | c.1322G>A p.R441Q | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445750983; called by muse, mutect2, varscan2
- DIP2B | c.3591C>G p.I1197M | Missense Mutation (SNP) | VAF 60/244 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV56582103; called by muse, mutect2, varscan2
- DLG2 | c.23C>T p.A8V | Missense Mutation (SNP) | VAF 35/282 reads (12%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0); catalogued as COSV101071642; called by muse, mutect2, varscan2
- DMD | c.9695G>T p.R3232L | Missense Mutation (SNP) | VAF 95/381 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as CM098343; called by muse, mutect2, varscan2
- DNASE1L2 | c.113C>T p.S38L | Missense Mutation (SNP) | VAF 33/117 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.034); catalogued as rs747353441, COSV57037572; called by muse, mutect2, varscan2
- DNMT3A | c.224C>G p.S75C | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0); catalogued as COSV53086026; called by muse, mutect2
- DPP10 | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 27/132 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867089720; called by muse, mutect2, varscan2
- DYRK3 | c.1337A>G p.K446R | Missense Mutation (SNP) | VAF 45/211 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.236); catalogued as rs782038854; called by muse, mutect2, varscan2
- EIF3H | c.944A>T p.D315V | Missense Mutation (SNP) | VAF 71/402 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.422); catalogued as rs1191681263; called by muse, mutect2, varscan2
- EPHA7 | c.2984G>T p.G995V | Missense Mutation (SNP) | VAF 20/96 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV65192918; called by muse, mutect2, varscan2
- ERICH3 | c.2930G>T p.G977V | Missense Mutation (SNP) | VAF 51/303 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.607); catalogued as rs1204804605, COSV58618179; called by muse, mutect2, varscan2
- ESRRG | c.1324G>T p.G442C | Missense Mutation (SNP) | VAF 41/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100753936; called by muse, mutect2, varscan2
- EYS | c.753G>T p.K251N | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.5); PolyPhen possibly damaging (0.624); catalogued as COSV60977268, COSV60982026, COSV61002672; called by muse, mutect2, varscan2
- FAM47B | c.194C>A p.P65H | Missense Mutation (SNP) | VAF 34/146 reads (23%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.994); catalogued as COSV61455355; called by muse, mutect2, varscan2
- FAM47C | c.161G>A p.G54D | Missense Mutation (SNP) | VAF 49/195 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.681); catalogued as COSV63725160; called by muse, mutect2, varscan2
- FAM50A | c.818G>A p.R273Q | Missense Mutation (SNP) | VAF 47/265 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.81); catalogued as COSV50131468; called by muse, mutect2, varscan2
- FBLN2 | c.3398G>T p.R1133L | Missense Mutation (SNP) | VAF 48/131 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as rs778004911; called by muse, mutect2, varscan2
- FBN2 | c.7547C>A p.S2516* | Nonsense Mutation (SNP) | VAF 68/400 reads (17%) | catalogued as COSV52514438; called by muse, mutect2, varscan2
- FETUB | c.898C>A p.P300T | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0.109); catalogued as COSV54004694; called by muse, mutect2
- FKRP | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 23/307 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1230638385; called by muse, mutect2
- FOXO1 | c.65C>A p.S22* | Nonsense Mutation (SNP) | VAF 18/143 reads (13%) | catalogued as COSV65426970; called by muse, mutect2, varscan2
- FOXQ1 | c.439G>T p.E147* | Nonsense Mutation (SNP) | VAF 30/131 reads (23%) | catalogued as COSV99723300; called by muse, mutect2, varscan2
- FUT4 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 42/114 reads (37%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as rs984644159, COSV62469209, COSV62469259, COSV62470017; called by muse, mutect2, varscan2
- GCNT4 | c.170G>C p.R57T | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.024); catalogued as COSV59280542; called by muse, mutect2, varscan2
- GFOD1 | c.770G>T p.R257L | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.688); catalogued as rs759860102, COSV64955200; called by muse, mutect2, varscan2
- GRIP1 | c.2526G>C p.Q842H (on ENST00000359742 / NM_001379345.1; = p.Q790H on NM_021150.4 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 91/460 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV54049125; called by muse, mutect2, varscan2
- H3-3A | c.139G>T p.V47L | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.009); catalogued as COSV64735013; called by muse, mutect2, varscan2
- H3C10 | c.191G>A p.R64K | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.37); catalogued as COSV60797419; called by muse, mutect2, varscan2
- HCN1 | c.1144G>T p.G382W | Missense Mutation (SNP) | VAF 81/607 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100301062; called by muse, mutect2, varscan2
- HDAC4 | c.1009G>A p.E337K | Missense Mutation (SNP) | VAF 14/365 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.231); catalogued as COSV100614145; called by muse, mutect2
- HEATR5B | c.5398C>G p.Q1800E | Missense Mutation (SNP) | VAF 50/270 reads (19%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV99249556; called by muse, mutect2, varscan2
- HERC1 | c.1735G>T p.D579Y | Missense Mutation (SNP) | VAF 16/102 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV71249811; called by muse, mutect2, varscan2
- HGSNAT | c.1546C>T p.L516F | Missense Mutation (SNP) | VAF 14/132 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.206); catalogued as rs1410277054; called by muse, mutect2, varscan2
- HNRNPA2B1 | c.569G>C p.R190T (on ENST00000354667 / NM_031243.3; = p.R178T on NM_002137.4) | Missense Mutation (SNP) | VAF 25/226 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.264); catalogued as COSV100522976; called by muse, mutect2, varscan2
- HRH3 | c.446C>A p.T149K | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.154); catalogued as rs755605299, COSV58048299, COSV58050728; called by muse, mutect2, varscan2
- IFNA10 | c.71G>A p.C24Y | Missense Mutation (SNP) | VAF 51/198 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs1389697006; called by muse, mutect2, varscan2
- IL9R | c.589C>A p.H197N | Missense Mutation (SNP) | VAF 27/152 reads (18%) | SIFT tolerated (0.18); PolyPhen benign (0.036); catalogued as COSV54902656; called by muse, mutect2, varscan2
- INHA | c.833G>T p.R278L | Missense Mutation (SNP) | VAF 89/362 reads (25%) | SIFT tolerated (0.05); PolyPhen benign (0.272); catalogued as COSV54712264; called by muse, mutect2, varscan2
- ITGA3 | c.2071-3C>T | Splice Region (SNP) | VAF 20/73 reads (27%) | catalogued as COSV99143995; called by muse, mutect2, varscan2
- KDELR2 | c.80G>A p.R27H | Missense Mutation (SNP) | VAF 11/132 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs1170984812; called by muse, mutect2
- KDM4E | c.685C>A p.P229T | Missense Mutation (SNP) | VAF 79/260 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV71678332; called by muse, mutect2, varscan2
- KLHDC7A | c.895C>T p.Q299* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as COSV68770396; called by muse, mutect2, varscan2
- KLHL36 | c.45G>C p.K15N | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.13); PolyPhen benign (0.076); catalogued as rs771528247, COSV50719949; called by muse, mutect2, varscan2
- KRTAP6-3 | c.221G>A p.R74K | Missense Mutation (SNP) | VAF 81/453 reads (18%) | PolyPhen benign (0.073); catalogued as COSV66963040; called by muse, mutect2, varscan2
- LAMA4 | c.5011G>C p.E1671Q (on ENST00000230538 / NM_001105206.3; = p.E1664Q on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 16/506 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100037591; called by muse, mutect2
- LECT2 | c.309C>G p.F103L | Missense Mutation (SNP) | VAF 19/86 reads (22%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV50847042; called by muse, mutect2, varscan2
- LRRC52 | c.625G>A p.D209N | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT tolerated (0.39); PolyPhen benign (0); catalogued as COSV54232337, COSV99674174; called by muse, mutect2, varscan2
- LRRC74A | c.446G>A p.G149D | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754002061; called by muse, mutect2, varscan2
- MAGEA8 | c.632T>A p.M211K | Missense Mutation (SNP) | VAF 53/218 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.229); catalogued as COSV99674777; called by muse, mutect2, varscan2
- MAGIX | c.826G>A p.A276T | Missense Mutation (SNP) | VAF 35/271 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.327); catalogued as COSV100891930; called by muse, mutect2, varscan2
- MAMDC4 | c.3493C>T p.L1165F (on ENST00000445819; = p.L1086F on NM_206920.3) | Missense Mutation (SNP) | VAF 54/229 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.018); catalogued as rs1564389542, COSV56377260; called by muse, mutect2, varscan2
- MARK4 | c.1772C>T p.P591L | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.36); catalogued as COSV53464052; called by muse, varscan2
- MAST2 | c.2383C>T p.R795C | Missense Mutation (SNP) | VAF 28/170 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as rs745570300; called by muse, mutect2, varscan2
- MBOAT1 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 22/174 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV61128268; called by muse, mutect2, varscan2
- MTMR4 | c.1091C>T p.P364L | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs371543773; called by muse, mutect2, varscan2
- MUC16 | c.33383C>G p.S11128* | Nonsense Mutation (SNP) | VAF 28/108 reads (26%) | catalogued as COSV67447245; called by muse, mutect2, varscan2
- MUC17 | c.1579G>A p.E527K | Missense Mutation (SNP) | VAF 52/155 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs1184754323; called by muse, mutect2, varscan2
- MXRA5 | c.5472G>T p.Q1824H | Missense Mutation (SNP) | VAF 26/241 reads (11%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as rs1373931859; called by muse, mutect2, varscan2
- MYO3A | c.3358G>C p.D1120H | Missense Mutation (SNP) | VAF 38/187 reads (20%) | SIFT tolerated (0.55); PolyPhen benign (0.009); catalogued as rs771429089; called by muse, mutect2, varscan2
- MYO3A | c.4221G>C p.K1407N | Missense Mutation (SNP) | VAF 28/136 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as rs1317184919, COSV56327091, COSV99780686; called by muse, mutect2, varscan2
- NELFE | c.844C>G p.P282A | Missense Mutation (SNP) | VAF 13/73 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0.202); catalogued as COSV64810571; called by muse, mutect2, varscan2
- NHS | c.4618G>A p.D1540N | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.049); catalogued as rs764495971, COSV101196979; called by muse, mutect2
- NOC2L | c.1012A>C p.I338L | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.083); catalogued as rs769123373; called by muse, mutect2, varscan2
- NOL11 | c.16G>A p.E6K | Missense Mutation (SNP) | VAF 25/163 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs764864587; called by muse, mutect2, varscan2
- NPPA | c.367C>T p.R123W | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs377057675, COSV56737928; called by muse, mutect2, varscan2
- NR1H4 | c.202C>G p.Q68E (on ENST00000551379 / NM_001206993.2; = p.Q58E on NM_005123.4) | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.001); catalogued as rs1320928669; called by muse, mutect2, varscan2
- NRDE2 | c.115C>G p.L39V | Missense Mutation (SNP) | VAF 21/212 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.341); catalogued as COSV62963038; called by muse, mutect2, varscan2
- NRK | c.3868G>C p.E1290Q | Missense Mutation (SNP) | VAF 25/144 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.425); catalogued as COSV99686205; called by muse, mutect2, varscan2
- OR12D3 | c.262A>T p.R88W | Missense Mutation (SNP) | VAF 49/186 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.825); catalogued as rs143467095; called by muse, mutect2, varscan2
- OR2T27 | c.618G>C p.M206I | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV61280530; called by mutect2, varscan2
- OR51Q1 | c.336G>A p.M112I | Missense Mutation (SNP) | VAF 58/286 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1309989985, COSV56177831; called by muse, mutect2, varscan2
- OR5H6 | c.251T>A p.F84Y (on ENST00000642105; = p.F68Y on NM_001005479.2) | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.864); catalogued as COSV101051789; called by muse, mutect2, varscan2
- OR6C3 | c.239G>A p.G80E | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.007); catalogued as rs752901236; called by muse, mutect2, varscan2
- PARD3B | c.3304C>T p.R1102W (on ENST00000406610 / NM_001302769.2; = p.R1033W on NM_057177.7) | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.781); catalogued as rs369194609; called by muse, mutect2, varscan2
- PAX5 | c.962C>A p.P321H | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs577863510; called by muse, mutect2, varscan2
- PCDHA6 | c.1306T>A p.W436R | Missense Mutation (SNP) | VAF 64/404 reads (16%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.026); catalogued as COSV65344123; called by muse, varscan2
- PCDHB2 | c.1331C>A p.S444Y | Missense Mutation (SNP) | VAF 102/679 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.987); catalogued as COSV50564015; called by muse, mutect2, varscan2
- PCDHB4 | c.1843G>T p.G615C | Missense Mutation (SNP) | VAF 105/504 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); catalogued as COSV99522508; called by muse, mutect2, varscan2
- PCDHGB5 | c.1190C>G p.S397W | Missense Mutation (SNP) | VAF 26/213 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); catalogued as COSV53973969; called by muse, varscan2
- PCDHGB5 | c.1234C>A p.P412T | Missense Mutation (SNP) | VAF 27/166 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.219); catalogued as rs375619778; called by muse, varscan2
- PCLO | c.11868G>T p.M3956I | Missense Mutation (SNP) | VAF 47/203 reads (23%) | SIFT tolerated (0.17); PolyPhen benign (0.194); catalogued as COSV100430745; called by muse, mutect2, varscan2
- PCLO | c.5850G>T p.M1950I | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.957); catalogued as COSV61639787; called by muse, mutect2, varscan2
- PDSS1 | c.309G>C p.L103F | Missense Mutation (SNP) | VAF 87/321 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as COSV66059558; called by muse, mutect2, varscan2
- PI4KA | c.4045C>T p.R1349C | Missense Mutation (SNP) | VAF 32/267 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs766536133; called by muse, mutect2, varscan2
- PLOD3 | c.148G>A p.E50K | Missense Mutation (SNP) | VAF 58/222 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.148); catalogued as rs752058315, COSV99777720; called by muse, mutect2, varscan2
- PRDM13 | c.1459G>A p.G487S | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as rs1276743205; called by muse, mutect2, varscan2
- PRKCG | c.1571C>A p.P524Q | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54725899, COSV54727705; called by muse, mutect2, varscan2
- PTPRN2 | c.2060C>T p.T687M | Missense Mutation (SNP) | VAF 30/143 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.835); catalogued as rs746049451; called by muse, mutect2, varscan2
- RAB7A | c.535G>A p.E179K | Missense Mutation (SNP) | VAF 87/512 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV54044554; called by muse, mutect2, varscan2
- RALGPS2 | c.1168A>G p.T390A | Missense Mutation (SNP) | VAF 69/411 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs774381829; called by muse, mutect2, varscan2
- RARS2 | c.1588C>T p.H530Y | Missense Mutation (SNP) | VAF 28/303 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as CM164755; called by muse, mutect2
- RB1 | c.2212-1G>C p.X738_splice | Splice Site (SNP) | VAF 21/99 reads (21%) | catalogued as CS1510793, CS890136, COSV57303754, COSV57310648; called by muse, mutect2, varscan2
- RERGL | c.26A>C p.Y9S | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as COSV57460694; called by muse, mutect2, varscan2
- RGS18 | c.230C>A p.P77H | Missense Mutation (SNP) | VAF 16/105 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV66509318, COSV66509744; called by muse, mutect2, varscan2
- RHCG | c.127G>C p.E43Q | Missense Mutation (SNP) | VAF 23/336 reads (7%) | SIFT tolerated (0.43); PolyPhen benign (0.062); catalogued as rs370877195, COSV51517916; called by muse, mutect2
- RHOU | c.706A>G p.K236E | Missense Mutation (SNP) | VAF 42/257 reads (16%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1300754187; called by muse, mutect2, varscan2
- RIMBP3B | c.4643G>T p.G1548V | Missense Mutation (SNP) | VAF 79/425 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.929); catalogued as rs1214869360; called by muse, mutect2, varscan2
- ROS1 | c.1528C>T p.L510F | Missense Mutation (SNP) | VAF 46/242 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.601); catalogued as rs1375443218, COSV63852834, COSV63857406; called by muse, mutect2, varscan2
- RP1L1 | c.1387G>T p.E463* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV66752367, COSV66755846; called by muse, mutect2, varscan2
- RREB1 | c.3062C>A p.S1021* | Nonsense Mutation (SNP) | VAF 11/56 reads (20%) | catalogued as COSV58552677; called by muse, mutect2, varscan2
- RRP15 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.012); catalogued as rs200861386, COSV65117502; called by muse, mutect2, varscan2
- RSPH9 | c.193G>A p.E65K | Missense Mutation (SNP) | VAF 48/266 reads (18%) | SIFT tolerated (0.67); PolyPhen benign (0); catalogued as rs3177328; called by muse, mutect2, varscan2
- RTL10 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 28/246 reads (11%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.998); catalogued as COSV60735450; called by muse, mutect2, varscan2
- RUFY1 | c.185G>T p.W62L | Missense Mutation (SNP) | VAF 31/172 reads (18%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.979); catalogued as COSV100105972; called by muse, mutect2, varscan2
- RYR2 | c.10189C>G p.R3397G | Missense Mutation (SNP) | VAF 37/239 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100771179, COSV99053554; called by muse, mutect2, varscan2
- RYR2 | c.10190G>C p.R3397P | Missense Mutation (SNP) | VAF 37/236 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63659008; called by muse, mutect2, varscan2
- SAMSN1 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.125); catalogued as COSV53477616; called by muse, varscan2
- SCLT1 | c.1310G>A p.R437K | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV99828120; called by muse, mutect2, varscan2
- SCLY | c.902G>A p.R301K (on ENST00000651534; = p.R293K on NM_016510.7) | Missense Mutation (SNP) | VAF 36/151 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs372075500; called by muse, mutect2, varscan2
- SEC16B | c.2545G>A p.G849S | Missense Mutation (SNP) | VAF 28/255 reads (11%) | SIFT tolerated (0.23); PolyPhen benign (0.023); catalogued as rs754367512; called by muse, mutect2
- SERPINA6 | c.507G>C p.Q169H | Missense Mutation (SNP) | VAF 79/456 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.222); catalogued as rs760494725; called by muse, mutect2, varscan2
- SERPINB6 | c.212A>C p.Q71P (on ENST00000612421 / NM_001271823.2; = p.Q52P on NM_004568.6) | Missense Mutation (SNP) | VAF 57/321 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100177391; called by muse, mutect2, varscan2
- SIMC1 | c.563G>T p.C188F (on ENST00000443967 / NM_001308196.1; = p.C207F on NM_001308195.2) | Missense Mutation (SNP) | VAF 26/130 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.369); catalogued as COSV57904385; called by muse, mutect2, varscan2
- SLC22A3 | c.1468C>T p.R490W | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1367005024, COSV51710530, COSV51718325; called by muse, mutect2, varscan2
- SLC6A17 | c.401A>G p.Y134C | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as rs780649225; called by muse, mutect2, varscan2
- SLC8A1 | c.1419G>C p.K473N | Missense Mutation (SNP) | VAF 22/87 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100246306, COSV60478909; called by muse, mutect2, varscan2
- SLC9B1 | c.1495C>G p.H499D | Missense Mutation (SNP) | VAF 26/940 reads (3%) | SIFT tolerated (0.42); PolyPhen benign (0.003); catalogued as COSV56474256; called by muse, mutect2
- SLFNL1 | c.176C>G p.S59* | Nonsense Mutation (SNP) | VAF 85/409 reads (21%) | catalogued as rs953493534; called by muse, mutect2, varscan2
- SLIT3 | c.4358T>C p.V1453A | Missense Mutation (SNP) | VAF 32/191 reads (17%) | SIFT tolerated (0.7); PolyPhen benign (0); catalogued as rs201812377; called by muse, mutect2, varscan2
- SNCAIP | c.1855A>C p.I619L | Missense Mutation (SNP) | VAF 68/596 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.322); catalogued as COSV54417761; called by muse, varscan2
- SNX9 | c.883G>A p.E295K | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.997); catalogued as COSV101093840; called by muse, mutect2, varscan2
- SOCS4 | c.946G>A p.E316K | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as rs1294477932; called by muse, mutect2
- SPNS1 | c.802G>T p.A268S | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.014); catalogued as rs769885665; called by muse, mutect2, varscan2
- SPTB | c.4127C>T p.S1376L | Missense Mutation (SNP) | VAF 61/430 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs200559187; called by muse, mutect2, varscan2
- STAG2 | c.37C>A p.L13I | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.018); catalogued as COSV99494887; called by muse, mutect2, varscan2
- SVEP1 | c.4939G>C p.D1647H | Missense Mutation (SNP) | VAF 26/140 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.78); catalogued as COSV65683987; called by muse, mutect2, varscan2
- SYDE2 | c.1622G>A p.R541Q | Missense Mutation (SNP) | VAF 10/60 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs561704514, COSV52316580; called by muse, mutect2, varscan2
- SYNPO2 | c.1853C>T p.A618V | Missense Mutation (SNP) | VAF 21/116 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs765298746; called by muse, mutect2, varscan2
- SZT2 | c.3310-1G>C p.X1104_splice (on ENST00000634258 / NM_001365999.1; = p.X1047_splice on NM_015284.4) | Splice Site (SNP) | VAF 32/132 reads (24%) | catalogued as COSV65171198; called by muse, mutect2, varscan2
- TAB3 | c.607C>A p.L203I | Missense Mutation (SNP) | VAF 64/274 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.06); catalogued as COSV55836506; called by muse, mutect2, varscan2
- TAS2R4 | c.426C>A p.F142L | Missense Mutation (SNP) | VAF 22/103 reads (21%) | SIFT tolerated (0.53); PolyPhen benign (0.009); catalogued as COSV56093206; called by muse, varscan2
- TBC1D30 | c.688C>G p.Q230E (on ENST00000542120; = p.Q67E on NM_015279.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/89 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.015); catalogued as rs1252659573; called by muse, mutect2, varscan2
- TBC1D9B | c.2911C>G p.Q971E | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT tolerated (0.98); PolyPhen benign (0); catalogued as rs200195260; called by muse, mutect2, varscan2
- TBX18 | c.55G>T p.A19S | Missense Mutation (SNP) | VAF 19/80 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs776741987; called by muse, mutect2, varscan2
- TECRL | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.01); catalogued as rs867978042, COSV67085544; called by muse, mutect2, varscan2
- TEX13C | c.2332C>A p.P778T | Missense Mutation (SNP) | VAF 59/437 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0); catalogued as rs1439801353; called by muse, mutect2, varscan2
- TEX55 | c.82A>G p.K28E | Missense Mutation (SNP) | VAF 21/183 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs930457205; called by muse, mutect2, varscan2
- TEX55 | c.465G>C p.E155D | Missense Mutation (SNP) | VAF 39/232 reads (17%) | SIFT tolerated (0.62); PolyPhen benign (0.147); catalogued as COSV55210124, COSV55213044; called by muse, mutect2, varscan2
- TFAP2B | c.1222C>G p.P408A | Missense Mutation (SNP) | VAF 54/359 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV53830965; called by muse, mutect2, varscan2
- TLR7 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV66125833; called by muse, mutect2
- TNFSF12-TNFSF13 | c.245C>A p.A82E | Missense Mutation (SNP) | VAF 36/198 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.01); catalogued as rs370085069; called by muse, mutect2, varscan2
- TNIK | c.386G>T p.W129L | Missense Mutation (SNP) | VAF 29/265 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as COSV52693630; called by muse, mutect2, varscan2
- TRANK1 | c.2305G>A p.D769N | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV57144526; called by muse, mutect2
- TTC7A | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 9/272 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1271340445; called by muse, mutect2
- TUBB | c.1075C>A p.R359S | Missense Mutation (SNP) | VAF 21/119 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.058); catalogued as COSV58358036; called by muse, mutect2, varscan2
- UACA | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as COSV100537644; called by muse, mutect2, varscan2
- UBASH3A | c.796G>A p.A266T | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs760045145; called by muse, mutect2, varscan2
- UGT2B4 | c.1265G>A p.S422N | Missense Mutation (SNP) | VAF 64/305 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.036); catalogued as COSV59319920, COSV59320441; called by muse, mutect2, varscan2
- ULK1 | c.42C>G p.F14L | Missense Mutation (SNP) | VAF 38/175 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.018); catalogued as COSV100416788; called by muse, mutect2, varscan2
- UNC79 | c.2368G>C p.D790H (on ENST00000393151 / NM_001346218.2; = p.D613H on NM_020818.5) | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV56390613; called by muse, varscan2
- UTP25 | c.1669G>T p.V557L | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.869); catalogued as rs1295519643; called by muse, mutect2, varscan2
- VPS13D | c.7066A>G p.T2356A | Missense Mutation (SNP) | VAF 65/382 reads (17%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV50622220; called by muse, mutect2, varscan2
- VWC2 | c.509C>G p.A170G | Missense Mutation (SNP) | VAF 71/314 reads (23%) | SIFT tolerated (0.33); PolyPhen benign (0.089); catalogued as COSV100514861, COSV61486085; called by muse, mutect2, varscan2
- WAC | c.1375C>G p.Q459E | Missense Mutation (SNP) | VAF 23/263 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.9); catalogued as COSV61567752, COSV61570303; called by muse, mutect2
- ZEB1 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 24/709 reads (3%) | SIFT tolerated (0.14); PolyPhen benign (0.025); catalogued as COSV99053888; called by muse, mutect2
- ZIC1 | c.713C>A p.P238H | Missense Mutation (SNP) | VAF 28/312 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV51552148; called by muse, mutect2
- ZNF112 | c.848G>C p.G283A (on ENST00000337401 / NM_001083335.2; = p.G277A on NM_013380.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.48); PolyPhen benign (0.239); catalogued as COSV61620625; called by muse, mutect2, varscan2
- ZNF135 | c.1828G>T p.D610Y (on ENST00000313434 / NM_001289401.2; = p.D622Y on NM_003436.4) | Missense Mutation (SNP) | VAF 55/158 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV99046659; called by muse, mutect2, varscan2
- ZNF394 | c.374G>A p.R125Q | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.918); catalogued as rs1312398521, COSV58744278; called by muse, mutect2, varscan2
- ZNF507 | c.2023G>T p.E675* | Nonsense Mutation (SNP) | VAF 30/214 reads (14%) | catalogued as COSV61331103; called by muse, mutect2, varscan2
- ZNF570 | c.1397G>C p.G466A | Missense Mutation (SNP) | VAF 28/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100356119; called by muse, varscan2
- ZNF831 | c.917C>T p.S306L | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as COSV64044601; called by muse, mutect2
- ZNF845 | c.387G>C p.R129S | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT tolerated (0.63); PolyPhen benign (0.013); catalogued as rs752292123; called by muse, mutect2, varscan2
- ZXDA | c.2146G>T p.E716* | Nonsense Mutation (SNP) | VAF 30/218 reads (14%) | catalogued as COSV99080945; called by muse, varscan2
- ABCA2 | c.253G>A p.A85T (on ENST00000614293; = p.X55_splice on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ABCF2 | c.1075A>T p.K359* | Nonsense Mutation (SNP) | VAF 55/331 reads (17%) | called by muse, mutect2, varscan2
- AC053503.6 | c.937C>A p.R313S | Missense Mutation (SNP) | VAF 26/110 reads (24%) | SIFT tolerated (0.89); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- ACCSL | c.905C>G p.T302S | Missense Mutation (SNP) | VAF 39/160 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- ACSM3 | c.1009G>A p.D337N | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.061); called by muse, mutect2, varscan2
- ADAMTS5 | c.2146C>A p.L716M | Missense Mutation (SNP) | VAF 33/205 reads (16%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS5 | c.1651G>T p.G551C | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADCY2 | c.1569C>G p.I523M | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.05); PolyPhen benign (0.065); called by muse, mutect2
- ADGB | c.4880T>A p.L1627* | Nonsense Mutation (SNP) | VAF 44/281 reads (16%) | called by muse, mutect2, varscan2
- AGMO | c.1237G>T p.V413F | Missense Mutation (SNP) | VAF 24/169 reads (14%) | SIFT tolerated (0.32); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- AHI1 | c.1671A>T p.K557N | Missense Mutation (SNP) | VAF 24/113 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.198); called by muse, mutect2, varscan2
- AHNAK2 | c.16556C>A p.S5519Y | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- AIFM3 | c.1521G>A p.M507I | Missense Mutation (SNP) | VAF 11/284 reads (4%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- AKAP13 | c.5349G>C p.E1783D (on ENST00000394518 / NM_007200.5; = p.E1787D on NM_006738.6) | Missense Mutation (SNP) | VAF 41/193 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- AKAP17A | c.415G>T p.E139* | Nonsense Mutation (SNP) | VAF 3/19 reads (16%) | called by muse, mutect2
- AKR1B1 | c.533A>G p.Y178C | Missense Mutation (SNP) | VAF 68/231 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- AMER1 | c.911C>A p.P304H | Missense Mutation (SNP) | VAF 19/97 reads (20%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMER1 | c.398C>A p.A133D | Missense Mutation (SNP) | VAF 74/315 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- AMPH | c.1931A>G p.Q644R | Missense Mutation (SNP) | VAF 40/268 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.338); called by muse, mutect2, varscan2
- ANK3 | c.5118G>T p.Q1706H | Missense Mutation (SNP) | VAF 9/198 reads (5%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); called by muse, mutect2
- ANKRD27 | c.1488del p.A497Pfs*15 | Frame Shift Del (DEL) | VAF 34/260 reads (13%) | called by mutect2, pindel, varscan2
- ANKRD28 | c.1119G>C p.M373I | Missense Mutation (SNP) | VAF 26/154 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ANLN | c.343G>A p.D115N | Missense Mutation (SNP) | VAF 82/394 reads (21%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANO4 | c.735-1G>T p.X245_splice (on ENST00000392977 / NM_001286615.2; = p.X210_splice on NM_178826.4) | Splice Site (SNP) | VAF 32/186 reads (17%) | called by muse, mutect2, varscan2
- APLNR | c.208A>T p.S70C | Missense Mutation (SNP) | VAF 27/118 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- APOB | c.4467G>C p.Q1489H | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- ARHGEF35 | c.1055C>A p.S352* | Nonsense Mutation (SNP) | VAF 48/493 reads (10%) | called by muse, varscan2
- ARMC3 | c.1192G>A p.D398N | Missense Mutation (SNP) | VAF 42/154 reads (27%) | SIFT tolerated (0.86); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ASPM | c.5986G>T p.A1996S | Missense Mutation (SNP) | VAF 24/250 reads (10%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.831); called by muse, mutect2
- ASXL3 | c.3982A>G p.S1328G | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ATF6 | c.1957C>A p.P653T | Missense Mutation (SNP) | VAF 20/115 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- ATF7IP | c.1426G>T p.G476C | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- ATP4A | c.1470G>C p.E490D | Missense Mutation (SNP) | VAF 32/153 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- ATR | c.5875dup p.R1959Kfs*10 | Frame Shift Ins (INS) | VAF 46/280 reads (16%) | called by pindel, varscan2
- B3GLCT | c.743A>T p.Y248F | Missense Mutation (SNP) | VAF 98/374 reads (26%) | SIFT tolerated (0.45); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- B4GALNT1 | c.1259A>G p.H420R | Missense Mutation (SNP) | VAF 31/200 reads (16%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- BAIAP2L2 | c.57C>G p.I19M | Missense Mutation (SNP) | VAF 31/103 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BLOC1S5 | c.131C>T p.S44L | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- BRAP | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 16/118 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.953); called by muse, mutect2, varscan2
- BTG2 | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 28/130 reads (22%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- C10orf105 | c.49del p.L17Sfs*40 | Frame Shift Del (DEL) | VAF 4/29 reads (14%) | called by mutect2, pindel
- C11orf80 | c.922C>G p.L308V | Missense Mutation (SNP) | VAF 20/143 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C12orf4 | c.1337G>T p.R446L | Missense Mutation (SNP) | VAF 48/293 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C12orf4 | c.1336C>A p.R446S | Missense Mutation (SNP) | VAF 48/291 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- C17orf75 | c.794G>T p.C265F | Missense Mutation (SNP) | VAF 34/213 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- C6orf118 | c.557G>A p.C186Y | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2, varscan2
- CASP5 | c.479C>A p.T160K | Missense Mutation (SNP) | VAF 22/108 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- CCDC50 | c.842A>T p.Q281L | Missense Mutation (SNP) | VAF 65/172 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- CCNL2 | c.183C>G p.F61L | Missense Mutation (SNP) | VAF 72/336 reads (21%) | SIFT tolerated (0.72); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- CCR4 | c.620A>T p.N207I | Missense Mutation (SNP) | VAF 32/106 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CD244 | c.46G>A p.V16M | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CDC40 | c.942+1G>A p.X314_splice | Splice Site (SNP) | VAF 31/223 reads (14%) | called by muse, mutect2, varscan2
- CDH2 | c.938C>G p.P313R | Missense Mutation (SNP) | VAF 17/320 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2
- CENPT | c.1537G>A p.E513K | Missense Mutation (SNP) | VAF 18/161 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.188); called by muse, mutect2, varscan2
- CFAP58 | c.1323G>C p.E441D | Missense Mutation (SNP) | VAF 15/108 reads (14%) | SIFT tolerated (0.06); PolyPhen benign (0.104); called by muse, mutect2
- CFAP91 | c.900G>C p.L300F | Missense Mutation (SNP) | VAF 32/154 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CFH | c.233G>T p.R78M | Missense Mutation (SNP) | VAF 39/247 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- CHAD | c.343C>T p.R115C | Missense Mutation (SNP) | VAF 41/188 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- CHAF1B | c.325G>T p.E109* | Nonsense Mutation (SNP) | VAF 39/253 reads (15%) | called by muse, mutect2, varscan2
- CHD8 | c.4432G>C p.D1478H (on ENST00000646647 / NM_001170629.2; = p.D1199H on NM_020920.4) | Missense Mutation (SNP) | VAF 31/196 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); called by muse, mutect2, varscan2
- CHKB | c.724G>A p.D242N | Missense Mutation (SNP) | VAF 129/418 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CHPT1 | c.394G>C p.D132H | Missense Mutation (SNP) | VAF 16/76 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CHRNB2 | c.1247C>T p.S416L | Missense Mutation (SNP) | VAF 29/135 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CLCN4 | c.1466A>T p.Q489L | Missense Mutation (SNP) | VAF 14/228 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2
- CLUAP1 | c.1239C>G p.F413L | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.952); called by muse, mutect2
- CNTNAP2 | c.2905A>C p.S969R | Missense Mutation (SNP) | VAF 113/511 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- COL4A2 | c.1194G>C p.Q398H | Missense Mutation (SNP) | VAF 23/117 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- COL6A5 | c.4087C>G p.L1363V | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CREM | c.287C>T p.T96I (on ENST00000429130; = p.T47I on NM_001881.3) | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- CTIF | c.1195G>A p.E399K | Missense Mutation (SNP) | VAF 13/361 reads (4%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.761); called by muse, mutect2
- CTTNBP2 | c.4986C>A p.N1662K | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- CYP26B1 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 73/327 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- DDX1 | c.709G>T p.E237* | Nonsense Mutation (SNP) | VAF 23/82 reads (28%) | called by muse, varscan2
- DIS3L | c.697G>C p.V233L (on ENST00000319212 / NM_001143688.3; = p.V150L on NM_133375.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.071); called by muse, mutect2, varscan2
- DLG2 | c.1572G>C p.M524I | Missense Mutation (SNP) | VAF 68/449 reads (15%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- DNAH5 | c.7713G>T p.R2571S | Missense Mutation (SNP) | VAF 55/369 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- DNAH8 | c.6283C>G p.Q2095E | Missense Mutation (SNP) | VAF 40/232 reads (17%) | SIFT tolerated (0.12); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- DPP8 | c.1384G>C p.E462Q (on ENST00000341861 / NM_001320875.2; = p.E446Q on NM_017743.6) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.01); called by muse, mutect2
- DPYD | c.599T>G p.I200R | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- DSG1 | c.562A>T p.N188Y | Missense Mutation (SNP) | VAF 32/219 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EDIL3 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 30/273 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- EFHC2 | c.1694A>G p.Q565R | Missense Mutation (SNP) | VAF 29/186 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- EIF2AK1 | c.1200G>T p.K400N | Missense Mutation (SNP) | VAF 30/152 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- EIF4G1 | c.3727G>C p.E1243Q (on ENST00000346169 / NM_198241.3; = p.E1048Q on NM_004953.5) | Missense Mutation (SNP) | VAF 22/352 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.55); called by muse, mutect2
- EMC1 | c.519C>G p.I173M | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ESRRG | c.1325G>T p.G442V | Missense Mutation (SNP) | VAF 41/226 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- EYS | c.40T>G p.F14V | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- F13B | c.1911C>G p.D637E | Missense Mutation (SNP) | VAF 26/176 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- FAAH2 | c.1441G>C p.G481R | Missense Mutation (SNP) | VAF 70/495 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.629); called by muse, mutect2, varscan2
- FAM104B | c.120+1G>C p.X40_splice | Splice Site (SNP) | VAF 18/80 reads (23%) | called by muse, mutect2, varscan2
- FAM162A | c.277G>C p.D93H | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.946); called by muse, mutect2
- FAM186A | c.150C>G p.I50M | Missense Mutation (SNP) | VAF 20/95 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.829); called by muse, mutect2, varscan2
- FAM205A | c.104A>C p.H35P | Missense Mutation (SNP) | VAF 18/89 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.498); called by muse, mutect2, varscan2
- FAS | c.421G>A p.E141K | Missense Mutation (SNP) | VAF 58/334 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.461); called by muse, mutect2, varscan2
- FAT3 | c.3001G>T p.E1001* | Nonsense Mutation (SNP) | VAF 45/186 reads (24%) | called by muse, mutect2, varscan2
- FAT4 | c.3121G>C p.G1041R | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- FLCN | c.1176+5G>C | Splice Region (SNP) | VAF 58/273 reads (21%) | called by muse, mutect2, varscan2
- FLNB | c.2521C>T p.P841S | Missense Mutation (SNP) | VAF 50/233 reads (21%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FNBP1L | c.1724G>T p.G575V (on ENST00000271234 / NM_001164473.2; = p.G517V on NM_017737.5) | Missense Mutation (SNP) | VAF 8/130 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- FOXH1 | c.769G>T p.G257C | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.541); called by muse, mutect2
- FOXO3 | c.538C>G p.L180V | Missense Mutation (SNP) | VAF 44/188 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- FRAS1 | c.1930G>T p.G644C | Missense Mutation (SNP) | VAF 58/349 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- FREM3 | c.160G>T p.G54C | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- FRG2C | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 46/776 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- FRMD8 | c.728A>T p.D243V | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRMPD4 | c.2761G>C p.E921Q | Missense Mutation (SNP) | VAF 15/194 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- GABRG2 | c.1337A>T p.Y446F (on ENST00000361925 / NM_001375343.1; = p.Y406F on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 68/425 reads (16%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GALC | c.992G>T p.W331L | Missense Mutation (SNP) | VAF 90/522 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- GART | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 24/120 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.354); called by mutect2, varscan2
- GATA1 | c.1162G>T p.G388C | Missense Mutation (SNP) | VAF 14/44 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.839); called by muse, mutect2, varscan2
- GJA3 | c.503A>G p.Y168C | Missense Mutation (SNP) | VAF 69/300 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); called by muse, varscan2
- GLYATL2 | c.120C>G p.F40L | Missense Mutation (SNP) | VAF 27/210 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- GPATCH8 | c.1640C>G p.T547S | Missense Mutation (SNP) | VAF 50/235 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- GPD1L | c.1012C>G p.Q338E | Missense Mutation (SNP) | VAF 68/268 reads (25%) | SIFT tolerated (0.75); PolyPhen benign (0); called by muse, varscan2
- GPR149 | c.447G>T p.Q149H | Missense Mutation (SNP) | VAF 16/181 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.478); called by muse, mutect2
- GPRIN3 | c.2101G>C p.D701H | Missense Mutation (SNP) | VAF 40/185 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GRIK2 | c.831_832insT p.G278Wfs*17 | Frame Shift Ins (INS) | VAF 24/137 reads (18%) | called by mutect2, pindel, varscan2
- GRIN2D | c.685G>A p.E229K | Missense Mutation (SNP) | VAF 27/85 reads (32%) | SIFT tolerated (0.51); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- HAVCR1 | c.131_134del p.S44Cfs*46 | Frame Shift Del (DEL) | VAF 13/70 reads (19%) | called by mutect2, pindel, varscan2
- HCN1 | c.1145G>T p.G382V | Missense Mutation (SNP) | VAF 82/605 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HHIP | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 27/183 reads (15%) | SIFT tolerated (0.58); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- HIP1R | c.2942T>C p.M981T | Missense Mutation (SNP) | VAF 39/166 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- HMGB4 | c.277C>T p.P93S | Missense Mutation (SNP) | VAF 48/208 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.993); called by muse, mutect2
- HR | c.2611-2A>G p.X871_splice | Splice Site (SNP) | VAF 74/249 reads (30%) | called by muse, mutect2, varscan2
- HYDIN | c.13838del p.G4613Efs*5 | Frame Shift Del (DEL) | VAF 43/331 reads (13%) | called by mutect2, pindel, varscan2
- IGHA1 | c.115G>A p.V39M | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.918); called by muse, mutect2
- IGHG4 | c.601T>G p.C201G | Missense Mutation (SNP) | VAF 18/213 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- IGKV6-21 | c.138G>T p.Q46H | Missense Mutation (SNP) | VAF 30/182 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.184); called by mutect2, varscan2
- IL31 | c.10C>A p.H4N | Missense Mutation (SNP) | VAF 13/242 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.423); called by muse, mutect2
- IL32 | c.515T>C p.V172A (on ENST00000396890 / NM_001308078.4; = p.V126A on NM_004221.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 36/344 reads (10%) | SIFT tolerated (0.73); PolyPhen benign (0); called by muse, mutect2
- IMPG1 | c.1307C>A p.P436Q | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0.04); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- INTS2 | c.2278G>C p.A760P | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2
- ISCU | c.219G>A p.M73I (on ENST00000311893 / NM_213595.4; = p.M48I on NM_014301.4) | Missense Mutation (SNP) | VAF 55/312 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ITGA1 | c.2405T>A p.I802N | Missense Mutation (SNP) | VAF 36/204 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ITGAL | c.3398A>T p.N1133I | Missense Mutation (SNP) | VAF 40/197 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- ITGB2 | c.1356C>G p.I452M (on ENST00000302347; = p.I428M on NM_000211.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 65/327 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- ITIH2 | c.950T>A p.V317E | Missense Mutation (SNP) | VAF 47/277 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- JHY | c.1031C>T p.P344L | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT tolerated (0.83); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- KAT6B | c.3610G>A p.E1204K | Missense Mutation (SNP) | VAF 41/190 reads (22%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.253); called by muse, mutect2, varscan2
- KCNK10 | c.559T>C p.Y187H | Missense Mutation (SNP) | VAF 19/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KCNK18 | c.721C>T p.Q241* | Nonsense Mutation (SNP) | VAF 44/225 reads (20%) | called by muse, mutect2, varscan2
- KDM4E | c.684C>A p.F228L | Missense Mutation (SNP) | VAF 78/255 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.124); called by muse, mutect2, varscan2
- KIF26A | c.5192G>T p.W1731L | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.23); called by muse, mutect2, varscan2
- KIF26B | c.160_168del p.P54_P56del | In Frame Del (DEL) | VAF 16/96 reads (17%) | called by mutect2, pindel, varscan2
- KIF2B | c.1538C>A p.S513Y | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- KLF13 | c.768G>T p.M256I | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.636); called by muse, mutect2, varscan2
- KLF9 | c.625G>C p.E209Q | Missense Mutation (SNP) | VAF 26/412 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); called by muse, mutect2
- KLHL34 | c.1363G>C p.A455P | Missense Mutation (SNP) | VAF 6/96 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2
- KNL1 | c.6898C>T p.H2300Y (on ENST00000346991 / NM_170589.5; = p.H2274Y on NM_144508.5) | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.929); called by muse, mutect2, varscan2
- KRTAP9-8 | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 126/616 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- LAMA1 | c.4297G>T p.V1433L | Missense Mutation (SNP) | VAF 109/410 reads (27%) | SIFT tolerated (0.48); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- LAMA2 | c.2046G>C p.K682N | Missense Mutation (SNP) | VAF 78/457 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.129); called by muse, mutect2, varscan2
- LARP4B | c.100C>T p.Q34* | Nonsense Mutation (SNP) | VAF 31/214 reads (14%) | called by muse, mutect2, varscan2
- LAS1L | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 29/176 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.75); called by muse, mutect2, varscan2
- LCAT | c.853G>C p.E285Q | Missense Mutation (SNP) | VAF 68/236 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.158); called by muse, varscan2
- LMLN | c.1765C>T p.H589Y | Missense Mutation (SNP) | VAF 64/483 reads (13%) | SIFT tolerated (0.41); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- LOXHD1 | c.2602G>C p.E868Q | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- LRCH2 | c.2270C>A p.T757N | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, varscan2
- LRP1 | c.8540C>G p.S2847C | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC39 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 8/62 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); called by muse, mutect2
- LRRC4C | c.1224T>A p.D408E | Missense Mutation (SNP) | VAF 46/149 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- LRRK2 | c.1418+1G>T p.X473_splice | Splice Site (SNP) | VAF 28/177 reads (16%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1038G>T p.Q346H | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MAGEA8 | c.435T>A p.N145K | Missense Mutation (SNP) | VAF 19/110 reads (17%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- MAGEB18 | c.516C>A p.H172Q | Missense Mutation (SNP) | VAF 45/186 reads (24%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- MAGEE1 | c.2101G>T p.E701* | Nonsense Mutation (SNP) | VAF 54/196 reads (28%) | called by muse, mutect2, varscan2
- MAMDC4 | c.3494T>C p.L1165P (on ENST00000445819; = p.L1086P on NM_206920.3) | Missense Mutation (SNP) | VAF 53/224 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- MAOB | c.316G>A p.V106I | Missense Mutation (SNP) | VAF 22/117 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAP4K3 | c.2118G>C p.Q706H | Missense Mutation (SNP) | VAF 9/160 reads (6%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.988); called by muse, mutect2
- MAPK12 | c.343G>C p.D115H | Missense Mutation (SNP) | VAF 39/112 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MARCHF9 | c.392C>T p.S131L | Missense Mutation (SNP) | VAF 38/160 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); called by muse, mutect2, varscan2
- MCM2 | c.2449-1G>T p.X817_splice | Splice Site (SNP) | VAF 19/98 reads (19%) | called by muse, mutect2, varscan2
- MDN1 | c.12826G>A p.A4276T | Missense Mutation (SNP) | VAF 23/107 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- MECOM | c.872T>G p.L291R (on ENST00000468789 / NM_001105078.4; = p.L479R on NM_004991.4) | Missense Mutation (SNP) | VAF 125/389 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, mutect2, varscan2
- MED14 | c.3634G>A p.G1212R | Missense Mutation (SNP) | VAF 32/235 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- METTL14 | c.67T>A p.L23M | Missense Mutation (SNP) | VAF 22/249 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.969); called by muse, mutect2
- MFAP3L | c.904G>A p.D302N | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MINDY4 | c.90G>T p.M30I | Missense Mutation (SNP) | VAF 67/326 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); called by muse, mutect2, varscan2
- MRC1 | c.342T>A p.D114E | Missense Mutation (SNP) | VAF 135/745 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- MROH2B | c.1978T>G p.C660G | Missense Mutation (SNP) | VAF 13/86 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- MSLNL | c.521C>G p.S174C | Missense Mutation (SNP) | VAF 48/164 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- MSS51 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 29/145 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MTR | c.2837C>G p.S946C | Missense Mutation (SNP) | VAF 52/304 reads (17%) | SIFT deleterious (0.03); PolyPhen benign (0.175); called by muse, mutect2, varscan2
- MUC16 | c.19163A>T p.D6388V | Missense Mutation (SNP) | VAF 40/118 reads (34%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- MUC3A | c.862C>A p.P288T | Missense Mutation (SNP) | VAF 55/201 reads (27%) | SIFT tolerated, low confidence (0.22); called by muse, mutect2, varscan2
- MVP | c.2146G>T p.V716L | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MYH11 | c.5722G>C p.D1908H | Missense Mutation (SNP) | VAF 40/172 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- MYO15A | c.8990C>G p.S2997C | Missense Mutation (SNP) | VAF 23/97 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); called by muse, mutect2, varscan2
- MZT2B | c.65G>T p.R22L | Missense Mutation (SNP) | VAF 19/85 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NADSYN1 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 54/278 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.94); called by muse, mutect2, varscan2
- NALCN | c.245A>G p.Y82C | Missense Mutation (SNP) | VAF 17/105 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- NANOS2 | c.250C>A p.P84T | Missense Mutation (SNP) | VAF 43/132 reads (33%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.522); called by muse, mutect2, varscan2
- NBPF15 | c.644A>T p.H215L | Missense Mutation (SNP) | VAF 132/736 reads (18%) | SIFT tolerated (0.17); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- NCCRP1 | c.89G>T p.R30L | Missense Mutation (SNP) | VAF 131/374 reads (35%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- NDE1 | c.458A>T p.E153V | Missense Mutation (SNP) | VAF 36/162 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NDN | c.840del p.R281Gfs*52 | Frame Shift Del (DEL) | VAF 9/45 reads (20%) | called by mutect2, pindel, varscan2
- NECTIN3 | c.1390G>C p.D464H | Missense Mutation (SNP) | VAF 22/95 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- NHS | c.1949C>A p.T650K | Missense Mutation (SNP) | VAF 14/202 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); called by muse, mutect2
- NLGN1 | c.2242C>T p.H748Y | Missense Mutation (SNP) | VAF 14/193 reads (7%) | SIFT tolerated, low confidence (0.76); PolyPhen possibly damaging (0.491); called by muse, mutect2
- NLRC5 | c.2866G>T p.E956* | Nonsense Mutation (SNP) | VAF 33/135 reads (24%) | called by muse, mutect2, varscan2
- NLRP5 | c.2789_2820del p.L930Pfs*41 | Frame Shift Del (DEL) | VAF 38/122 reads (31%) | called by mutect2, pindel
- NME3 | c.316G>C p.A106P | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.17); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NOXO1 | c.148-3C>G | Splice Region (SNP) | VAF 4/60 reads (7%) | called by muse, mutect2
- NPC1L1 | c.2142C>G p.I714M | Missense Mutation (SNP) | VAF 57/289 reads (20%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- NPL | c.55A>T p.M19L | Missense Mutation (SNP) | VAF 65/323 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- NSD2 | c.2436C>G p.I812M | Missense Mutation (SNP) | VAF 34/157 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- NUDT11 | c.492C>A p.P164= | Splice Region (SNP) | VAF 17/48 reads (35%) | called by muse, mutect2, varscan2
- NUP210L | c.1262T>A p.I421K | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT tolerated (0.27); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- NUTM2B | c.2289C>A p.F763L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT deleterious (0.01); PolyPhen benign (0.335); called by mutect2, varscan2
- OLFM1 | c.1009G>A p.D337N (on ENST00000371793 / NM_001282611.2; = p.D319N on NM_014279.5) | Missense Mutation (SNP) | VAF 46/192 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- OR13G1 | c.156G>T p.L52F | Missense Mutation (SNP) | VAF 50/325 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR2D2 | c.536G>C p.C179S | Missense Mutation (SNP) | VAF 9/105 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR2T1 | c.381C>A p.N127K | Missense Mutation (SNP) | VAF 27/130 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- OR2T4 | c.111C>A p.N37K | Missense Mutation (SNP) | VAF 97/476 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.342); called by muse, mutect2, varscan2
- OR5L1 | c.361G>A p.D121N | Missense Mutation (SNP) | VAF 14/177 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.32); called by muse, mutect2
- OR6A2 | c.782T>A p.I261N | Missense Mutation (SNP) | VAF 50/256 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- OTOGL | c.437C>G p.S146C (on ENST00000547103; = p.S137C on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- P3H3 | c.799G>A p.E267K | Missense Mutation (SNP) | VAF 12/36 reads (33%) | SIFT tolerated (0.15); PolyPhen benign (0.255); called by muse, mutect2, varscan2
- PACSIN2 | c.976C>G p.L326V | Missense Mutation (SNP) | VAF 19/90 reads (21%) | SIFT deleterious (0.02); PolyPhen benign (0.289); called by muse, mutect2, varscan2
- PCDHA1 | c.841T>C p.F281L | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- PCDHB14 | c.2161T>A p.S721T | Missense Mutation (SNP) | VAF 57/269 reads (21%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PCDHB4 | c.1844G>T p.G615V | Missense Mutation (SNP) | VAF 101/500 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- PCM1 | c.5792C>G p.S1931C | Missense Mutation (SNP) | VAF 27/99 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PGM5 | c.1477C>A p.Q493K | Missense Mutation (SNP) | VAF 27/108 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- PHYHD1 | c.758C>G p.S253C (on ENST00000372592 / NM_001100876.2; = p.L246V on NM_174933.4) | Missense Mutation (SNP) | VAF 24/133 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PLAC9 | c.184C>T p.H62Y | Missense Mutation (SNP) | VAF 65/241 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PLD4 | c.792C>G p.Y264* | Nonsense Mutation (SNP) | VAF 65/266 reads (24%) | called by muse, mutect2, varscan2
- PLSCR5 | c.722C>T p.P241L | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- PML | c.2532_2551delinsA p.A845Kfs*37 | Frame Shift Del (DEL) | VAF 30/200 reads (15%) | called by pindel, varscan2*
- PNMA1 | c.9G>T p.M3I | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, varscan2
- POLA1 | c.164C>A p.T55K | Missense Mutation (SNP) | VAF 14/136 reads (10%) | SIFT tolerated (0.34); PolyPhen benign (0.403); called by muse, mutect2
- POLR3A | c.2176G>C p.E726Q | Missense Mutation (SNP) | VAF 89/487 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- POTEH | c.399C>A p.S133R | Missense Mutation (SNP) | VAF 88/1210 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.303); called by muse, varscan2
- PRDM9 | c.193+1G>T p.X65_splice | Splice Site (SNP) | VAF 110/336 reads (33%) | called by muse, mutect2, varscan2
- PREX1 | c.4298G>A p.S1433N | Missense Mutation (SNP) | VAF 63/216 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- PROM2 | c.2178G>C p.V726= | Splice Region (SNP) | VAF 10/159 reads (6%) | called by muse, mutect2
- PSD2 | c.299G>A p.R100K | Missense Mutation (SNP) | VAF 72/278 reads (26%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- PSD2 | c.1077G>T p.L359F | Missense Mutation (SNP) | VAF 33/142 reads (23%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- PTGES | c.167C>T p.P56L | Missense Mutation (SNP) | VAF 7/133 reads (5%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2
- PTX4 | c.304G>C p.A102P (on ENST00000447419 / NM_001328608.2; = p.A97P on NM_001013658.1) | Missense Mutation (SNP) | VAF 14/212 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.085); called by muse, mutect2
- QTRT2 | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 25/150 reads (17%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.542); called by muse, mutect2, varscan2
- RAB40AL | c.494A>G p.E165G | Missense Mutation (SNP) | VAF 76/329 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- RAPGEF2 | c.1223G>T p.G408V | Missense Mutation (SNP) | VAF 57/385 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RARRES2 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- RBKS | c.274G>A p.D92N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2
- RBM15 | c.2108G>C p.R703T | Missense Mutation (SNP) | VAF 34/188 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- REM1 | c.205G>A p.E69K | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.34); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- RERGL | c.458C>T p.S153F | Missense Mutation (SNP) | VAF 35/197 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- RGS22 | c.625G>T p.A209S | Missense Mutation (SNP) | VAF 22/126 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0); called by muse, mutect2, varscan2
- RGS7 | c.1270-1G>T p.X424_splice | Splice Site (SNP) | VAF 26/211 reads (12%) | called by muse, mutect2, varscan2
- RGS7 | c.611C>A p.P204H | Missense Mutation (SNP) | VAF 44/337 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- RIDA | c.352-2A>T p.X118_splice | Splice Site (SNP) | VAF 24/126 reads (19%) | called by muse, mutect2, varscan2
- RIPK2 | c.1169G>C p.G390A | Missense Mutation (SNP) | VAF 26/174 reads (15%) | SIFT tolerated (0.55); PolyPhen benign (0); called by muse, mutect2, varscan2
- RNF139 | c.259C>G p.L87V | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.13); PolyPhen benign (0.355); called by muse, mutect2, varscan2
- RPS6KA5 | c.1119G>T p.Q373H | Missense Mutation (SNP) | VAF 11/73 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.793); called by muse, mutect2, varscan2
- RSF1 | c.3796G>C p.E1266Q | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- RTL6 | c.501G>T p.Q167H | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.63); called by muse, mutect2, varscan2
- RTN1 | c.559G>T p.D187Y | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- SACS | c.6283A>T p.T2095S | Missense Mutation (SNP) | VAF 30/139 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- SAP30L | c.331C>G p.L111V | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- SCART1 | c.977C>T p.S326L | Missense Mutation (SNP) | VAF 56/330 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- SCN2B | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 88/313 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- SCN3A | c.5198C>A p.P1733H | Missense Mutation (SNP) | VAF 98/392 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SCN3A | c.1982C>G p.S661* | Nonsense Mutation (SNP) | VAF 9/212 reads (4%) | called by muse, mutect2
- SEC16B | c.2546G>T p.G849V | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.255); called by muse, mutect2
- SEL1L3 | c.2021G>T p.G674V | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- SEPTIN4 | c.1342G>C p.E448Q | Missense Mutation (SNP) | VAF 44/189 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); called by muse, mutect2, varscan2
- SERAC1 | c.1382G>A p.R461K | Missense Mutation (SNP) | VAF 45/255 reads (18%) | SIFT tolerated (0.72); PolyPhen benign (0.012); called by muse, varscan2
- SERINC1 | c.187G>C p.E63Q | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.53); PolyPhen benign (0.026); called by muse, mutect2
- SHROOM3 | c.3301G>T p.A1101S | Missense Mutation (SNP) | VAF 66/313 reads (21%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SIAH3 | c.643del p.E215Rfs*14 | Frame Shift Del (DEL) | VAF 45/188 reads (24%) | called by mutect2, pindel, varscan2
- SIX4 | c.1288T>A p.S430T | Missense Mutation (SNP) | VAF 43/212 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- SLC15A3 | c.344C>G p.S115W | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.79); called by muse, mutect2, varscan2
- SLC20A2 | c.286G>T p.V96F | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.023); called by mutect2, varscan2
- SLC24A3 | c.985G>A p.G329S | Missense Mutation (SNP) | VAF 50/238 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.222); called by muse, mutect2, varscan2
- SLC25A31 | c.568G>C p.G190R | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.707); called by muse, mutect2, varscan2
- SLC26A5 | c.1801G>T p.G601* | Nonsense Mutation (SNP) | VAF 46/250 reads (18%) | called by muse, varscan2
- SLC27A4 | c.1708G>A p.E570K | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- SLC4A11 | c.1709G>C p.G570A | Missense Mutation (SNP) | VAF 58/178 reads (33%) | SIFT tolerated (0.39); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- SPIB | c.42C>A p.F14L | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPRY2 | c.584T>A p.L195Q | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- SPTB | c.2794C>G p.L932V | Missense Mutation (SNP) | VAF 61/260 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- SRP72 | c.655G>T p.E219* | Nonsense Mutation (SNP) | VAF 22/98 reads (22%) | called by muse, mutect2, varscan2
- SRP72 | c.1402A>T p.S468C | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- SRPX | c.460A>G p.K154E | Missense Mutation (SNP) | VAF 38/239 reads (16%) | SIFT tolerated (1); PolyPhen possibly damaging (0.721); called by muse, mutect2, varscan2
- SSBP3 | c.993G>A p.M331I (on ENST00000371320 / NM_145716.4; = p.M311I on NM_018070.5) | Missense Mutation (SNP) | VAF 29/142 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- STK32C | c.422C>T p.P141L | Missense Mutation (SNP) | VAF 34/169 reads (20%) | PolyPhen possibly damaging (0.856); called by muse, mutect2, varscan2
- STOX2 | c.1543G>C p.G515R | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.221); called by muse, mutect2, varscan2
- STRN3 | c.976G>T p.G326C | Missense Mutation (SNP) | VAF 34/150 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SUPT20HL1 | c.79A>T p.R27* | Nonsense Mutation (SNP) | VAF 8/180 reads (4%) | called by muse, mutect2
- SUPT6H | c.2760C>G p.I920M | Missense Mutation (SNP) | VAF 40/281 reads (14%) | SIFT tolerated (0.65); PolyPhen benign (0.029); called by muse, mutect2, varscan2
- SYCP1 | c.2154+1G>T p.X718_splice | Splice Site (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2, varscan2
- SYT4 | c.748A>G p.R250G | Missense Mutation (SNP) | VAF 24/182 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TAB2 | c.140C>G p.S47C | Missense Mutation (SNP) | VAF 34/163 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- TAS2R4 | c.522C>G p.I174M | Missense Mutation (SNP) | VAF 18/95 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.076); called by muse, varscan2
- TBC1D32 | c.3045G>T p.M1015I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.026); called by muse, varscan2
- TBK1 | c.1208A>G p.H403R | Missense Mutation (SNP) | VAF 23/116 reads (20%) | SIFT tolerated (0.35); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TBRG4 | c.813del p.S272Pfs*19 | Frame Shift Del (DEL) | VAF 52/258 reads (20%) | called by mutect2, pindel, varscan2
- TDRD15 | c.5175_5188del p.W1726Kfs*2 | Frame Shift Del (DEL) | VAF 4/33 reads (12%) | called by mutect2, pindel
- TENM1 | c.107C>A p.P36Q | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TERF1 | c.508G>T p.E170* | Nonsense Mutation (SNP) | VAF 21/114 reads (18%) | called by muse, mutect2, varscan2
- TEX13A | c.451C>A p.H151N | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT tolerated (0.46); PolyPhen benign (0.242); called by muse, mutect2, varscan2
- THEMIS | c.1202G>C p.C401S | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- THSD7B | c.2806G>C p.D936H | Missense Mutation (SNP) | VAF 51/252 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- TKTL1 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 26/138 reads (19%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMEM260 | c.1112G>T p.G371V | Missense Mutation (SNP) | VAF 52/276 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- TNK2 | c.628C>G p.L210V | Missense Mutation (SNP) | VAF 11/70 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2
- TPD52 | c.259G>C p.E87Q (on ENST00000379097 / NM_001025252.3; = p.E47Q on NM_005079.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/133 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); called by muse, mutect2
- TRAV10 | c.53-1G>T p.X18_splice | Splice Site (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- TRIM48 | c.308G>A p.S103N | Missense Mutation (SNP) | VAF 74/432 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.111); called by muse, varscan2
- TRIM48 | c.409C>A p.H137N | Missense Mutation (SNP) | VAF 89/450 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- TRMT2A | c.1611_1621del p.C538Gfs*15 | Frame Shift Del (DEL) | VAF 33/363 reads (9%) | called by mutect2, pindel
- TRO | c.2440G>T p.G814C | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); called by muse, mutect2, varscan2
- TRO | c.2441G>T p.G814V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); called by muse, mutect2, varscan2
- TRPA1 | c.2209G>C p.V737L | Missense Mutation (SNP) | VAF 14/133 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- TRPM6 | c.3239C>G p.S1080* | Nonsense Mutation (SNP) | VAF 52/224 reads (23%) | called by muse, mutect2, varscan2
- TSGA10IP | c.1147A>T p.T383S | Missense Mutation (SNP) | VAF 20/88 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TSHR | c.268C>G p.Q90E | Missense Mutation (SNP) | VAF 49/298 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- TSPEAR | c.1502C>A p.T501N | Missense Mutation (SNP) | VAF 47/250 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- TSPEAR | c.565G>T p.A189S | Missense Mutation (SNP) | VAF 39/198 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TTN | c.64354G>C p.D21452H (on ENST00000591111; = p.D14028H on NM_003319.4) | Missense Mutation (SNP) | VAF 30/159 reads (19%) | PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- TYSND1 | c.253G>T p.V85L | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.191); called by muse, mutect2, varscan2
- UBQLN3 | c.1705G>C p.E569Q | Missense Mutation (SNP) | VAF 34/151 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- UCMA | c.305A>G p.E102G | Missense Mutation (SNP) | VAF 38/139 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- UGGT1 | c.4346C>G p.S1449* | Nonsense Mutation (SNP) | VAF 42/133 reads (32%) | called by muse, mutect2, varscan2
- UGT3A2 | c.1444G>A p.E482K | Missense Mutation (SNP) | VAF 64/484 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); called by muse, mutect2, varscan2
- UNC5A | c.950T>C p.V317A | Missense Mutation (SNP) | VAF 28/107 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- USP53 | c.1583C>T p.S528F | Missense Mutation (SNP) | VAF 15/116 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); called by muse, mutect2, varscan2
- UTP25 | c.1669-1G>T p.X557_splice | Splice Site (SNP) | VAF 21/98 reads (21%) | called by muse, mutect2, varscan2
- VCAN | c.841G>A p.G281R | Missense Mutation (SNP) | VAF 41/259 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- VLDLR | c.1480T>A p.F494I | Missense Mutation (SNP) | VAF 51/191 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- VN1R4 | c.332C>G p.S111C | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- VPS13B | c.2877C>G p.I959M | Missense Mutation (SNP) | VAF 49/292 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- WDR13 | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 16/128 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- WDR97 | c.3279dup p.G1094Wfs*77 | Frame Shift Ins (INS) | VAF 4/29 reads (14%) | called by mutect2, pindel
- ZFHX2 | c.6055G>A p.E2019K | Missense Mutation (SNP) | VAF 31/168 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.32); called by muse, mutect2, varscan2
- ZFHX4 | c.6911A>G p.Y2304C | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZIC4 | c.427C>A p.L143I | Missense Mutation (SNP) | VAF 39/265 reads (15%) | SIFT tolerated (0.42); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ZNF182 | c.100G>T p.V34L | Missense Mutation (SNP) | VAF 28/192 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.579); called by muse, mutect2, varscan2
- ZNF26 | c.52G>T p.D18Y | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ZNF346 | c.704-2A>T p.X235_splice | Splice Site (SNP) | VAF 42/136 reads (31%) | called by muse, mutect2, varscan2
- ZNF385B | c.76G>C p.E26Q | Missense Mutation (SNP) | VAF 21/88 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.765); called by muse, mutect2
- ZNF418 | c.1419G>T p.Q473H | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.66); called by muse, mutect2, varscan2
- ZNF519 | c.497C>A p.S166* | Nonsense Mutation (SNP) | VAF 3/29 reads (10%) | called by muse, mutect2
- ZNF577 | c.659G>T p.G220V | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ZNF605 | c.55G>A p.E19K | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); called by muse, mutect2, varscan2
- ZNF70 | c.212C>G p.S71* | Nonsense Mutation (SNP) | VAF 9/168 reads (5%) | called by muse, mutect2
- ZNF727 | c.596G>T p.S199I | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZPBP2 | c.679G>C p.E227Q (on ENST00000348931 / NM_199321.3; = p.E205Q on NM_198844.3) | Missense Mutation (SNP) | VAF 39/245 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.785); called by muse, mutect2, varscan2
- ZXDB | c.671G>T p.C224F | Missense Mutation (SNP) | VAF 42/113 reads (37%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- ZZZ3 | c.1570C>G p.L524V | Missense Mutation (SNP) | VAF 33/225 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2, varscan2
- ABCA9 | c.4755C>T p.L1585= | Silent (SNP) | VAF 41/280 reads (15%) | catalogued as rs1567906316, COSV60626075; called by muse, mutect2, varscan2
- ABL2 | c.2304C>A p.P768= (on ENST00000502732 / NM_007314.4; = p.P753= on NM_005158.5) | Silent (SNP) | VAF 43/353 reads (12%) | called by muse, mutect2, varscan2
- ACACA | c.2064C>T p.F688= | Silent (SNP) | VAF 55/313 reads (18%) | catalogued as rs775343674; called by muse, mutect2, varscan2
- ADAM19 | c.948C>A p.L316= | Silent (SNP) | VAF 50/259 reads (19%) | called by muse, mutect2, varscan2
- ADAM9 | c.1551C>T p.C517= | Silent (SNP) | VAF 17/116 reads (15%) | called by muse, mutect2, varscan2
- ADAMTSL2 | c.1551G>C p.L517= | Silent (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- ADGRB2 | c.1635G>A p.K545= | Silent (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- AGBL5 | c.2142T>G p.P714= | Silent (SNP) | VAF 46/204 reads (23%) | called by muse, mutect2, varscan2
- ALDH3A1 | c.1173C>T p.V391= | Silent (SNP) | VAF 9/127 reads (7%) | called by muse, mutect2
- ALOX5 | c.480C>T p.C160= | Silent (SNP) | VAF 39/265 reads (15%) | called by muse, mutect2, varscan2
- AOX1 | c.771C>T p.F257= | Silent (SNP) | VAF 42/181 reads (23%) | catalogued as COSV101022168; called by muse, mutect2, varscan2
- AP1M1 | c.1026G>A p.V342= | Silent (SNP) | VAF 18/57 reads (32%) | called by muse, mutect2, varscan2
- ASAP2 | c.2916C>T p.I972= | Silent (SNP) | VAF 26/126 reads (21%) | catalogued as rs369291652; called by muse, mutect2, varscan2
- ASTN2 | c.1326G>T p.V442= (on ENST00000313400 / NM_001365069.1; = p.V391= on NM_014010.5) | Silent (SNP) | VAF 25/148 reads (17%) | called by muse, mutect2, varscan2
- ATAD2 | c.3132G>C p.L1044= | Silent (SNP) | VAF 10/53 reads (19%) | catalogued as COSV54886009; called by muse, mutect2, varscan2
- BANK1 | c.2238A>T p.P746= | Silent (SNP) | VAF 37/212 reads (17%) | called by muse, mutect2, varscan2
- BPIFC | c.43C>T p.L15= | Silent (SNP) | VAF 51/189 reads (27%) | called by muse, mutect2, varscan2
- BRINP3 | c.894C>A p.A298= | Silent (SNP) | VAF 22/186 reads (12%) | catalogued as COSV100819631; called by muse, mutect2, varscan2
- BTBD18 | c.489T>A p.P163= | Silent (SNP) | VAF 37/188 reads (20%) | called by muse, mutect2, varscan2
- C8A | c.1527C>A p.I509= | Silent (SNP) | VAF 94/504 reads (19%) | called by muse, mutect2, varscan2
- CADM4 | c.192C>G p.L64= | Silent (SNP) | VAF 10/65 reads (15%) | catalogued as COSV55929502; called by muse, mutect2, varscan2
- CAPS2 | c.1287A>G p.K429= | Silent (SNP) | VAF 16/67 reads (24%) | called by muse, mutect2
- CCDC168 | c.13860C>T p.I4620= | Silent (SNP) | VAF 17/101 reads (17%) | called by muse, mutect2, varscan2
- CCDC24 | c.753C>G p.L251= | Silent (SNP) | VAF 41/171 reads (24%) | called by muse, mutect2, varscan2
- CDH18 | c.396T>C p.D132= | Silent (SNP) | VAF 79/519 reads (15%) | called by muse, mutect2, varscan2
- CDH24 | c.2409C>G p.L803= | Silent (SNP) | VAF 24/138 reads (17%) | called by muse, mutect2, varscan2
- CDHR2 | c.1299G>A p.V433= | Silent (SNP) | VAF 35/186 reads (19%) | called by muse, mutect2, varscan2
- CFHR2 | c.639T>C p.I213= | Silent (SNP) | VAF 12/64 reads (19%) | called by muse, mutect2, varscan2
- CLIP2 | c.1458G>C p.R486= | Silent (SNP) | VAF 48/155 reads (31%) | called by muse, mutect2, varscan2
- CLIP2 | c.2922C>A p.L974= | Silent (SNP) | VAF 9/110 reads (8%) | called by muse, mutect2
- CNP | c.388C>A p.R130= | Silent (SNP) | VAF 43/270 reads (16%) | catalogued as COSV66368332; called by muse, mutect2, varscan2
- COL20A1 | c.426G>A p.G142= | Silent (SNP) | VAF 22/85 reads (26%) | catalogued as rs895217261, COSV58926202, COSV58928330; called by muse, mutect2, varscan2
- COL6A5 | c.2802C>G p.L934= | Silent (SNP) | VAF 32/370 reads (9%) | called by muse, mutect2
- CRYBG1 | c.1092C>T p.A364= | Silent (SNP) | VAF 19/77 reads (25%) | called by muse, mutect2, varscan2
- DAAM2 | c.1026A>T p.L342= | Silent (SNP) | VAF 36/179 reads (20%) | called by muse, mutect2, varscan2
- DCST2 | c.1227C>T p.T409= | Silent (SNP) | VAF 32/157 reads (20%) | catalogued as COSV55050971; called by muse, mutect2, varscan2
- DDB1 | c.606C>T p.F202= | Silent (SNP) | VAF 23/473 reads (5%) | called by muse, mutect2
- DERL1 | c.309C>G p.L103= | Silent (SNP) | VAF 29/181 reads (16%) | catalogued as COSV52365322; called by muse, mutect2, varscan2
- DMD | c.5820G>T p.G1940= | Silent (SNP) | VAF 23/102 reads (23%) | catalogued as rs1404360892, COSV63798730; called by muse, mutect2, varscan2
- DNAH17 | c.12490C>T p.L4164= | Silent (SNP) | VAF 72/374 reads (19%) | called by muse, mutect2, varscan2
- DNAH6 | c.1995C>A p.P665= | Silent (SNP) | VAF 34/242 reads (14%) | catalogued as COSV99406724; called by muse, mutect2, varscan2
- DNAJC6 | c.504G>T p.R168= | Silent (SNP) | VAF 11/54 reads (20%) | called by muse, mutect2
- EDA2R | c.342T>G p.S114= | Silent (SNP) | VAF 22/123 reads (18%) | catalogued as rs1395503615; called by muse, mutect2, varscan2
- EPHA6 | c.2457C>A p.I819= (on ENST00000389672 / NM_001080448.3; = p.I211= on NM_173655.4) | Silent (SNP) | VAF 16/154 reads (10%) | catalogued as COSV67579492; called by muse, mutect2, varscan2
- EPHB1 | c.606T>C p.N202= | Silent (SNP) | VAF 52/136 reads (38%) | called by muse, mutect2, varscan2
- ERBB4 | c.3886C>T p.L1296= | Silent (SNP) | VAF 30/134 reads (22%) | called by muse, mutect2, varscan2
- FAM120C | c.1431A>G p.E477= | Silent (SNP) | VAF 22/157 reads (14%) | called by muse, mutect2, varscan2
- FAM124B | c.306T>A p.T102= | Silent (SNP) | VAF 10/99 reads (10%) | called by muse, mutect2, varscan2
- FAM47C | c.2142C>T p.L714= | Silent (SNP) | VAF 85/388 reads (22%) | catalogued as COSV63723502; called by muse, mutect2, varscan2
- FBN2 | c.8469C>G p.P2823= | Silent (SNP) | VAF 12/89 reads (13%) | catalogued as COSV52536426; called by muse, mutect2, varscan2
- FBXO10 | c.114C>A p.L38= | Silent (SNP) | VAF 54/181 reads (30%) | catalogued as COSV52836767; called by mutect2, varscan2
- FCRLA | c.1116G>T p.R372= (on ENST00000367959; = p.R349= on NM_032738.4) | Silent (SNP) | VAF 20/100 reads (20%) | called by muse, varscan2
- FGF12 | c.253C>T p.L85= (on ENST00000454309 / NM_021032.5; = p.L23= on NM_004113.6) | Silent (SNP) | VAF 62/318 reads (19%) | catalogued as rs767118656; called by muse, mutect2, varscan2
- FMN2 | c.831C>A p.S277= | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- GABRA3 | c.1221G>T p.L407= | Silent (SNP) | VAF 56/275 reads (20%) | catalogued as COSV64796857; called by muse, mutect2, varscan2
- GABRG1 | c.222C>A p.G74= | Silent (SNP) | VAF 10/82 reads (12%) | catalogued as rs1197045400, COSV54954514; called by muse, mutect2, varscan2
- GPR153 | c.585C>G p.L195= | Silent (SNP) | VAF 41/165 reads (25%) | catalogued as rs1474657068; called by muse, mutect2, varscan2
- GPR32 | c.813G>T p.P271= | Silent (SNP) | VAF 22/91 reads (24%) | catalogued as rs1367255766, COSV54513965; called by muse, mutect2, varscan2
- GRID1 | c.324C>A p.A108= | Silent (SNP) | VAF 42/181 reads (23%) | called by muse, mutect2, varscan2
- H4C9 | c.138C>T p.R46= | Silent (SNP) | VAF 51/309 reads (17%) | catalogued as rs771531425; called by muse, mutect2, varscan2
- HCN4 | c.2319C>T p.I773= | Silent (SNP) | VAF 8/32 reads (25%) | called by muse, mutect2
- INPP4B | c.2736C>T p.Y912= | Silent (SNP) | VAF 28/175 reads (16%) | called by muse, mutect2, varscan2
- IQSEC3 | c.327C>A p.P109= | Silent (SNP) | VAF 26/161 reads (16%) | called by mutect2, varscan2
- ITGAE | c.3507G>A p.L1169= | Silent (SNP) | VAF 76/157 reads (48%) | called by muse, mutect2, varscan2
- JAML | c.861G>A p.L287= (on ENST00000356289 / NM_001098526.2; = p.L277= on NM_153206.3) | Silent (SNP) | VAF 28/135 reads (21%) | called by muse, mutect2, varscan2
- KCNB1 | c.1689G>A p.E563= | Silent (SNP) | VAF 15/68 reads (22%) | called by muse, mutect2, varscan2
- KCNH7 | c.1197G>A p.T399= | Silent (SNP) | VAF 36/137 reads (26%) | catalogued as rs775414148; called by muse, mutect2, varscan2
- KCNK9 | c.408G>A p.V136= | Silent (SNP) | VAF 48/270 reads (18%) | called by muse, mutect2, varscan2
- KCTD16 | c.1119C>A p.S373= | Silent (SNP) | VAF 76/464 reads (16%) | called by muse, mutect2, varscan2
- KHDC1L | c.372G>A p.P124= | Silent (SNP) | VAF 29/176 reads (16%) | catalogued as COSV64893258; called by muse, mutect2, varscan2
- KHDC1L | c.24C>T p.L8= | Silent (SNP) | VAF 31/216 reads (14%) | called by muse, mutect2, varscan2
- KIF19 | c.1074C>G p.S358= | Silent (SNP) | VAF 22/143 reads (15%) | catalogued as COSV100739061; called by muse, mutect2, varscan2
- LRCH2 | c.2271C>A p.T757= | Silent (SNP) | VAF 25/154 reads (16%) | called by muse, varscan2
- MAGEA1 | c.72C>A p.G24= | Silent (SNP) | VAF 20/95 reads (21%) | called by muse, mutect2, varscan2
- MAP3K14 | c.2394C>T p.L798= | Silent (SNP) | VAF 44/269 reads (16%) | catalogued as rs778794691; called by muse, mutect2, varscan2
- MAP3K15 | c.3549C>T p.L1183= | Silent (SNP) | VAF 13/36 reads (36%) | called by muse, mutect2, varscan2
- MAU2 | c.96C>T p.F32= | Silent (SNP) | VAF 63/195 reads (32%) | called by muse, mutect2, varscan2
- MED14 | c.2445C>A p.T815= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100247365; called by muse, mutect2
- MRC2 | c.2556C>T p.I852= | Silent (SNP) | VAF 46/244 reads (19%) | catalogued as COSV100316113; called by muse, mutect2, varscan2
- MRGPRG | c.744C>T p.L248= | Silent (SNP) | VAF 10/117 reads (9%) | called by muse, mutect2
- MXRA5 | c.1356A>T p.L452= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- MYO3A | c.3540G>A p.E1180= | Silent (SNP) | VAF 45/273 reads (16%) | catalogued as rs767521111; called by muse, mutect2, varscan2
- NCAM2 | c.2151G>A p.V717= | Silent (SNP) | VAF 83/431 reads (19%) | called by muse, mutect2, varscan2
- NRROS | c.468C>G p.L156= | Silent (SNP) | VAF 33/133 reads (25%) | called by muse, mutect2, varscan2
- OASL | c.1314G>A p.V438= | Silent (SNP) | VAF 35/171 reads (20%) | called by muse, mutect2, varscan2
- OR2A7 | c.129C>A p.T43= | Silent (SNP) | VAF 45/825 reads (5%) | called by muse, mutect2
- OR2L5 | c.828C>T p.F276= | Silent (SNP) | VAF 64/281 reads (23%) | called by muse, mutect2, varscan2
- OR2T12 | c.909G>T p.L303= | Silent (SNP) | VAF 36/132 reads (27%) | catalogued as COSV58777151; called by muse, mutect2
- OR2V1 | c.783G>A p.L261= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as COSV61458824; called by muse, mutect2, varscan2
- OR4B1 | c.225C>A p.I75= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as rs778929536, COSV58882336, COSV58884151; called by muse, mutect2, varscan2
- OR5A1 | c.156C>T p.I52= | Silent (SNP) | VAF 58/307 reads (19%) | catalogued as COSV100118353; called by muse, mutect2, varscan2
- OR6B3 | c.84C>T p.F28= | Silent (SNP) | VAF 7/71 reads (10%) | called by muse, mutect2, varscan2
- PCDHA1 | c.1293C>T p.G431= | Silent (SNP) | VAF 55/322 reads (17%) | called by muse, mutect2, varscan2
- PCDHB12 | c.1932C>G p.V644= | Silent (SNP) | VAF 25/360 reads (7%) | called by muse, mutect2, varscan2
- PCDHB6 | c.1503G>T p.L501= | Silent (SNP) | VAF 95/515 reads (18%) | called by muse, mutect2, varscan2
- PCDHB9 | c.756A>G p.P252= | Silent (SNP) | VAF 29/110 reads (26%) | called by muse, mutect2, varscan2
- PCNX3 | c.4020C>G p.L1340= | Silent (SNP) | VAF 30/154 reads (19%) | catalogued as COSV63137900; called by muse, mutect2, varscan2
- PCYT1B | c.931C>T p.L311= | Silent (SNP) | VAF 12/154 reads (8%) | catalogued as COSV100770729; called by muse, mutect2
- PDE10A | c.2220C>G p.T740= | Silent (SNP) | VAF 51/259 reads (20%) | catalogued as COSV63100654; called by muse, mutect2, varscan2
- PGBD1 | c.1341T>C p.N447= | Silent (SNP) | VAF 31/236 reads (13%) | called by muse, mutect2, varscan2
- PIM3 | c.396C>G p.L132= | Silent (SNP) | VAF 54/172 reads (31%) | called by muse, mutect2, varscan2
- PITX2 | c.411G>A p.R137= (on ENST00000354925 / NM_001204397.1; = p.R144= on NM_000325.6) | Silent (SNP) | VAF 9/100 reads (9%) | called by muse, mutect2
- PLA2G2E | c.147T>A p.G49= | Silent (SNP) | VAF 41/179 reads (23%) | called by muse, mutect2, varscan2
- PLEKHG4B | c.1215C>G p.L405= (on ENST00000283426; = p.L761= on NM_052909.5) | Silent (SNP) | VAF 14/64 reads (22%) | called by muse, mutect2, varscan2
- PLEKHH2 | c.2994C>T p.Y998= | Silent (SNP) | VAF 31/141 reads (22%) | called by muse, mutect2, varscan2
- PNLIPRP2 | c.1029C>A p.T343= | Silent (SNP) | VAF 14/74 reads (19%) | called by muse, mutect2, varscan2
- PPARGC1B | c.1932C>G p.L644= | Silent (SNP) | VAF 10/66 reads (15%) | called by muse, mutect2, varscan2
- PPIG | c.207C>G p.V69= | Silent (SNP) | VAF 32/220 reads (15%) | called by muse, mutect2, varscan2
- PPP1R3D | c.114G>A p.P38= | Silent (SNP) | VAF 4/15 reads (27%) | called by muse, mutect2, varscan2
- PRDM9 | c.225T>C p.C75= | Silent (SNP) | VAF 77/548 reads (14%) | called by muse, mutect2, varscan2
- PREX1 | c.741G>A p.L247= | Silent (SNP) | VAF 37/123 reads (30%) | called by muse, mutect2, varscan2
- PTGFRN | c.102G>T p.V34= | Silent (SNP) | VAF 18/118 reads (15%) | catalogued as rs762799999; called by muse, mutect2
- PTH | c.69G>A p.S23= | Silent (SNP) | VAF 49/228 reads (21%) | catalogued as rs377308600; ClinVar: benign; called by muse, mutect2, varscan2
- RALYL | c.612C>A p.T204= | Silent (SNP) | VAF 24/160 reads (15%) | called by muse, varscan2
- RBFA | c.135C>G p.L45= | Silent (SNP) | VAF 12/222 reads (5%) | called by muse, mutect2
- RNF207 | c.1161C>T p.S387= | Silent (SNP) | VAF 37/163 reads (23%) | called by muse, mutect2, varscan2
- ROS1 | c.1428C>A p.V476= | Silent (SNP) | VAF 33/151 reads (22%) | catalogued as COSV63854295; called by muse, mutect2, varscan2
- RTP5 | c.555C>A p.G185= | Silent (SNP) | VAF 6/21 reads (29%) | called by muse, mutect2, varscan2
- SCARF1 | c.2028C>T p.A676= | Silent (SNP) | VAF 20/101 reads (20%) | called by muse, mutect2, varscan2
- SEMA5B | c.414C>T p.L138= | Silent (SNP) | VAF 51/177 reads (29%) | catalogued as rs764954750, COSV99530835; called by muse, mutect2, varscan2
- SEPTIN4 | c.561C>A p.V187= | Silent (SNP) | VAF 36/145 reads (25%) | catalogued as COSV58728976; called by muse, mutect2, varscan2
- SLC1A7 | c.669G>A p.L223= | Silent (SNP) | VAF 16/94 reads (17%) | catalogued as rs1206425484; called by mutect2, varscan2
- SLC27A6 | c.903G>A p.K301= | Silent (SNP) | VAF 29/224 reads (13%) | catalogued as rs758691158, COSV52487628; called by muse, mutect2, varscan2
- SLC30A10 | c.258G>T p.A86= | Silent (SNP) | VAF 48/244 reads (20%) | called by muse, mutect2, varscan2
- SMG8 | c.2091G>A p.L697= | Silent (SNP) | VAF 22/123 reads (18%) | called by muse, mutect2, varscan2
- SMO | c.597G>C p.R199= | Silent (SNP) | VAF 68/297 reads (23%) | called by muse, mutect2, varscan2
- SOGA3 | c.465G>C p.S155= | Silent (SNP) | VAF 3/8 reads (38%) | catalogued as rs1233242267; called by muse, mutect2
- SPHKAP | c.2139T>G p.L713= | Silent (SNP) | VAF 10/165 reads (6%) | called by muse, mutect2
- STIP1 | c.1631G>A p.*544= | Silent (SNP) | VAF 22/87 reads (25%) | called by muse, mutect2, varscan2
- TAS1R2 | c.2001C>T p.R667= | Silent (SNP) | VAF 141/611 reads (23%) | catalogued as rs202082109; called by muse, mutect2, varscan2
- TCHH | c.1380C>T p.R460= | Silent (SNP) | VAF 50/224 reads (22%) | called by muse, varscan2
- TEX13C | c.331C>T p.L111= | Silent (SNP) | VAF 53/260 reads (20%) | catalogued as rs760331944; called by muse, mutect2, varscan2
- TFIP11 | c.678G>A p.R226= | Silent (SNP) | VAF 35/268 reads (13%) | called by muse, mutect2, varscan2
- TMEM132C | c.2925C>A p.G975= | Silent (SNP) | VAF 16/102 reads (16%) | called by muse, mutect2, varscan2
- TMEM132D | c.2709G>T p.G903= | Silent (SNP) | VAF 63/303 reads (21%) | catalogued as COSV67160101; called by muse, mutect2, varscan2
- TRAK2 | c.2454G>A p.L818= | Silent (SNP) | VAF 67/213 reads (31%) | called by muse, mutect2, varscan2
- TRIM39 | c.1440C>T p.I480= | Silent (SNP) | VAF 43/348 reads (12%) | called by muse, mutect2, varscan2
- TRIM51GP | c.108G>T p.R36= | Silent (SNP) | VAF 66/513 reads (13%) | called by muse, varscan2
- TRIM67 | c.2118C>A p.T706= | Silent (SNP) | VAF 4/14 reads (29%) | called by muse, mutect2, varscan2
- TRPA1 | c.1797C>A p.I599= | Silent (SNP) | VAF 83/497 reads (17%) | called by muse, mutect2, varscan2
- TTC3 | c.1860G>C p.V620= | Silent (SNP) | VAF 22/133 reads (17%) | called by muse, mutect2, varscan2
- TYMS | c.534C>A p.I178= | Silent (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- UBE2M | c.507G>T p.R169= | Silent (SNP) | VAF 48/182 reads (26%) | called by muse, mutect2, varscan2
- UMOD | c.924G>C p.S308= | Silent (SNP) | VAF 87/418 reads (21%) | catalogued as rs762457368, COSV56774592; called by muse, mutect2, varscan2
- UNC79 | c.7473C>A p.V2491= (on ENST00000393151 / NM_001346218.2; = p.V2314= on NM_020818.5) | Silent (SNP) | VAF 78/453 reads (17%) | catalogued as COSV99829716; called by muse, mutect2, varscan2
- URB1 | c.3693C>A p.L1231= | Silent (SNP) | VAF 27/123 reads (22%) | called by muse, mutect2, varscan2
- USP51 | c.633G>T p.L211= | Silent (SNP) | VAF 10/252 reads (4%) | catalogued as COSV72351705; called by muse, mutect2
- UTP14A | c.525C>G p.L175= | Silent (SNP) | VAF 26/112 reads (23%) | catalogued as COSV64087818; called by muse, mutect2, varscan2
- VAX1 | c.948C>T p.F316= | Silent (SNP) | VAF 63/281 reads (22%) | called by muse, mutect2, varscan2
- VPS33A | c.1485C>T p.L495= | Silent (SNP) | VAF 48/254 reads (19%) | catalogued as rs1354266418, COSV57359273; called by muse, mutect2, varscan2
- WDR41 | c.762C>G p.T254= | Silent (SNP) | VAF 68/371 reads (18%) | called by muse, mutect2, varscan2
- WSCD2 | c.627C>A p.G209= | Silent (SNP) | VAF 54/249 reads (22%) | called by muse, mutect2, varscan2
- ZBP1 | c.351C>G p.L117= | Silent (SNP) | VAF 64/169 reads (38%) | catalogued as COSV59064981; called by muse, mutect2, varscan2
- ZNF341 | c.966C>G p.L322= (on ENST00000375200 / NM_001282935.1; = p.L315= on NM_032819.4) | Silent (SNP) | VAF 21/105 reads (20%) | catalogued as rs1418500314, COSV61010225; called by muse, mutect2, varscan2
- ZNF385A | c.939G>A p.L313= (on ENST00000338010 / NM_001130967.3; = p.L293= on NM_015481.3) | Silent (SNP) | VAF 38/203 reads (19%) | called by muse, mutect2, varscan2
- ZNF497 | c.951C>T p.L317= | Silent (SNP) | VAF 5/40 reads (13%) | catalogued as rs548852162; called by muse, mutect2, varscan2
- ZXDA | c.2145A>T p.P715= | Silent (SNP) | VAF 30/223 reads (13%) | called by muse, varscan2
- ABCC13 | n.3655G>T | RNA (SNP) | VAF 4/37 reads (11%) | called by muse, mutect2
- AC107023.1 | n.25+486G>C | Intron (SNP) | VAF 11/78 reads (14%) | called by muse, mutect2, varscan2
- AC114741.1 | n.234C>A | RNA (SNP) | VAF 31/141 reads (22%) | called by muse, mutect2, varscan2
- ADAM3A | n.1610C>A | RNA (SNP) | VAF 50/247 reads (20%) | called by muse, mutect2, varscan2
- ADAMTS8 | chr11:130401922 C>A | 3'Flank (SNP) | VAF 79/269 reads (29%) | called by muse, mutect2, varscan2
- ADGRA1 | c.4-3750G>T | Intron (SNP) | VAF 31/137 reads (23%) | called by muse, mutect2, varscan2
- ADGRA1 | c.4-1307G>A | Intron (SNP) | VAF 30/102 reads (29%) | catalogued as rs752686449, COSV66929776; called by muse, mutect2, varscan2
- AL353804.4 | chrX:73821939 G>T | 5'Flank (SNP) | VAF 27/117 reads (23%) | called by muse, mutect2, varscan2
- AL353804.6 | n.109C>A | RNA (SNP) | VAF 59/315 reads (19%) | called by muse, mutect2, varscan2
- ARNTL | c.180-133C>A | Intron (SNP) | VAF 51/258 reads (20%) | called by muse, varscan2
- ATP6V0E2 | chr7:149873991 C>A | 5'Flank (SNP) | VAF 51/177 reads (29%) | called by muse, mutect2, varscan2
- B3GAT1 | c.-157C>A | 5'UTR (SNP) | VAF 35/122 reads (29%) | called by muse, mutect2, varscan2
- BICDL2 | chr16:3036256 A>G | 5'Flank (SNP) | VAF 15/91 reads (16%) | catalogued as rs943713929; called by muse, mutect2, varscan2
- BLACAT1 | c.-36-7338_-36-7337del | Intron (DEL) | VAF 19/120 reads (16%) | called by mutect2, pindel, varscan2
- BLACE | n.1718G>C | RNA (SNP) | VAF 36/175 reads (21%) | called by muse, mutect2, varscan2
- BOLL | c.*11C>A | 3'UTR (SNP) | VAF 28/144 reads (19%) | called by muse, mutect2, varscan2
- C11orf40 | n.551C>G | RNA (SNP) | VAF 42/200 reads (21%) | called by muse, mutect2, varscan2
- C3orf22 | chr3:126549569 G>C | 3'Flank (SNP) | VAF 20/149 reads (13%) | catalogued as rs1252469924; called by muse, mutect2, varscan2
- C6orf201 | c.-430C>G | 5'UTR (SNP) | VAF 9/38 reads (24%) | called by muse, mutect2, varscan2
- C7orf26 | c.1148+566C>T | Intron (SNP) | VAF 22/132 reads (17%) | catalogued as rs1303789571; called by muse, mutect2, varscan2
- CALM3 | c.-82G>C | 5'UTR (SNP) | VAF 16/52 reads (31%) | called by muse, mutect2, varscan2
- CAST | c.-26C>G | 5'UTR (SNP) | VAF 22/205 reads (11%) | called by muse, mutect2, varscan2
- CCDC88C | c.4442-2242C>G | Intron (SNP) | VAF 69/370 reads (19%) | catalogued as rs1055496229; called by muse, mutect2, varscan2
- CELA1 | c.-36C>A | 5'UTR (SNP) | VAF 30/153 reads (20%) | called by muse, mutect2, varscan2
- CLDN1 | c.-44C>T | 5'UTR (SNP) | VAF 39/183 reads (21%) | called by muse, mutect2, varscan2
- CPLX2 | c.*124C>A | 3'UTR (SNP) | VAF 20/117 reads (17%) | called by muse, mutect2, varscan2
- CREB3L2 | c.103-26896G>C | Intron (SNP) | VAF 37/146 reads (25%) | called by muse, mutect2, varscan2
- CSHL1 | c.471+91C>A | Intron (SNP) | VAF 70/290 reads (24%) | catalogued as rs767063106; called by muse, mutect2, varscan2
- CSMD3 | c.178+59918C>A | Intron (SNP) | VAF 96/644 reads (15%) | called by muse, mutect2, varscan2
- CTNNA3 | c.1047+3407G>T | Intron (SNP) | VAF 28/190 reads (15%) | called by muse, mutect2, varscan2
- CUL4B | c.68-24C>A | Intron (SNP) | VAF 29/165 reads (18%) | called by muse, mutect2, varscan2
- DIP2A | c.3498+240C>T | Intron (SNP) | VAF 32/189 reads (17%) | called by muse, mutect2, varscan2
77 further variants in this file (0 protein-altering or splice-affecting, 0 silent, 77 other) are not listed here.
